Somatic mutation profile of tumor specimen TCGA-EB-A5UN-06A (aliquot TCGA-EB-A5UN-06A-11D-A30X-08) from TCGA case TCGA-EB-A5UN, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 53.1 years (19,406 days).
Specimen TCGA-EB-A5UN-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 35430b36-7ed2-426d-95c0-ffc9d354fec3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EB-A5UN-10A (Blood Derived Normal), aliquot TCGA-EB-A5UN-10A-01D-A30X-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b5d526fd-32e4-4a0a-a9bf-ff3b86819541

The open-access MAF lists 865 somatic variants for this specimen: 571 protein-altering or splice-affecting, 275 silent, 19 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 500, Silent 275, Nonsense Mutation 45, Splice Region 13, RNA 8, Intron 8, Splice Site 7, Frame Shift Del 4, 3'Flank 3, Frame Shift Ins 2.

Variants (750 of 865; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 29/93 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- TF | c.1180G>A p.E394K | Missense Mutation (SNP) | VAF 28/102 reads (27%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.845); catalogued as rs121918680, CM024626, COSV53917909; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCA12 | c.4748A>G p.N1583S (on ENST00000272895 / NM_173076.3; = p.N1265S on NM_015657.3) | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV55966924; called by muse, varscan2
- ABCA5 | c.2779G>T p.D927Y | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); catalogued as COSV67017820; called by muse, mutect2, varscan2
- ABCC8 | c.988G>A p.E330K | Missense Mutation (SNP) | VAF 39/176 reads (22%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as COSV56846607; called by muse, mutect2, varscan2
- AC005833.1 | c.1198G>A p.E400K | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT tolerated, low confidence (0.97); catalogued as COSV52899198, COSV52899545; called by muse, mutect2, varscan2
- ACADL | c.281G>A p.G94E | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1033124874, COSV52054365; called by muse, mutect2, varscan2
- ACLY | c.573C>G p.F191L | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as COSV61251622; called by muse, mutect2, varscan2
- ACOT4 | c.688G>A p.G230S | Missense Mutation (SNP) | VAF 25/135 reads (19%) | SIFT tolerated (0.2); PolyPhen probably damaging (1); catalogued as COSV58335917; called by muse, mutect2, varscan2
- ADAM21 | c.2138C>T p.P713L | Missense Mutation (SNP) | VAF 15/109 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV50792874; called by muse, mutect2, varscan2
- ADAM29 | c.1321C>T p.L441F | Missense Mutation (SNP) | VAF 22/98 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1267071600, COSV63665628; called by muse, mutect2, varscan2
- ADAMTS6 | c.3268G>A p.A1090T | Missense Mutation (SNP) | VAF 16/86 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV58684116; called by muse, mutect2, varscan2
- ADGRE3 | c.1348A>G p.N450D | Missense Mutation (SNP) | VAF 22/102 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV53732576; called by muse, mutect2, varscan2
- ADGRG4 | c.5456C>T p.S1819L | Missense Mutation (SNP) | VAF 34/75 reads (45%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54961481, COSV99796359; called by muse, mutect2, varscan2
- ADGRL4 | c.314C>T p.T105I | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.82); catalogued as rs1214790794, COSV66063067; called by muse, mutect2, varscan2
- ADGRV1 | c.11688G>A p.M3896I | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV67985610; called by muse, mutect2, varscan2
- ADORA3 | c.384G>A p.W128* | Nonsense Mutation (SNP) | VAF 21/105 reads (20%) | catalogued as COSV53986411; called by muse, mutect2, varscan2
- AFM | c.634T>A p.Y212N | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT tolerated (0.85); PolyPhen possibly damaging (0.474); catalogued as COSV56921102; called by muse, mutect2, varscan2
- AFM | c.1414G>A p.D472N | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as COSV56921111; called by muse, mutect2, varscan2
- AGFG1 | c.1090C>T p.P364S | Missense Mutation (SNP) | VAF 13/97 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV59513321; called by muse, mutect2, varscan2
- AGO1 | c.1858C>T p.P620S | Missense Mutation (SNP) | VAF 19/91 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as COSV64595807; called by muse, mutect2, varscan2
- AGO3 | c.1570C>T p.P524S | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as COSV55794993; called by muse, mutect2, varscan2
- AGPS | c.1698-1G>A p.X566_splice | Splice Site (SNP) | VAF 11/70 reads (16%) | catalogued as COSV51570061; called by muse, mutect2
- AGPS | c.1698G>A p.R566= | Splice Region (SNP) | VAF 11/72 reads (15%) | catalogued as COSV99931629; called by muse, mutect2
- AKTIP | c.125C>T p.S42F | Missense Mutation (SNP) | VAF 23/118 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.459); catalogued as COSV55815955; called by muse, mutect2, varscan2
- ALKBH3 | c.800A>T p.E267V | Missense Mutation (SNP) | VAF 29/115 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.065); catalogued as COSV57025138; called by muse, mutect2, varscan2
- ALMS1 | c.7342C>T p.P2448S | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); catalogued as COSV52508882; called by muse, mutect2, varscan2
- ALPL | c.474G>A p.G158= | Splice Region (SNP) | VAF 7/47 reads (15%) | catalogued as rs868361054, COSV66379762; called by muse, mutect2, varscan2
- ANGPT1 | c.1270G>A p.D424N | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT tolerated (0.57); PolyPhen benign (0.04); catalogued as rs753406610, COSV52447456; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.5542C>T p.P1848S | Missense Mutation (SNP) | VAF 26/139 reads (19%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.021); catalogued as COSV51852642; called by muse, mutect2, varscan2
- ANKRD13C | c.1468C>T p.L490F | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as COSV52032991; called by muse, mutect2
- ANKRD16 | c.922C>T p.R308* | Nonsense Mutation (SNP) | VAF 7/19 reads (37%) | catalogued as rs774806484, COSV51947720, COSV99510373; called by muse, mutect2, varscan2
- ANXA10 | c.195G>A p.R65= | Splice Region (SNP) | VAF 16/46 reads (35%) | catalogued as COSV63739556; called by muse, mutect2, varscan2
- AOAH | c.1013C>T p.S338L | Missense Mutation (SNP) | VAF 20/133 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.777); catalogued as COSV51745588; called by muse, mutect2, varscan2
- APC2 | c.2997T>A p.Y999* | Nonsense Mutation (SNP) | VAF 8/23 reads (35%) | catalogued as COSV52020197, COSV52022564; called by muse, mutect2, varscan2
- APOB | c.9434C>T p.P3145L | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.172); catalogued as COSV51943163; called by muse, mutect2, varscan2
- APP | c.1750C>T p.P584S | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT tolerated (0.8); PolyPhen benign (0.024); catalogued as rs748858141, COSV61001119; called by muse, mutect2, varscan2
- ARAP2 | c.1685G>A p.R562K | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV58289191; called by muse, mutect2
- ARAP2 | c.836C>T p.S279F | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.58); catalogued as COSV58289195; called by muse, mutect2, varscan2
- ARFGAP3 | c.431C>T p.P144L | Missense Mutation (SNP) | VAF 46/226 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1300247948, COSV54312939; called by muse, mutect2, varscan2
- ARNT | c.1385C>T p.T462I | Missense Mutation (SNP) | VAF 40/113 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.7); catalogued as COSV62231429; called by muse, mutect2, varscan2
- ASH1L | c.6232C>T p.R2078C (on ENST00000368346 / NM_001366177.2; = p.R2073C on NM_018489.3) | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.009); catalogued as rs772388982, COSV64204956; called by muse, mutect2, varscan2
- ASIC4 | c.847G>A p.E283K | Missense Mutation (SNP) | VAF 17/110 reads (15%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.531); catalogued as rs1459689251, COSV61732459; called by muse, mutect2, varscan2
- ASMT | c.145G>A p.V49M | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.83); catalogued as COSV67110076; called by muse, mutect2, varscan2
- ATAD5 | c.1018C>T p.P340S | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.727); catalogued as COSV58976544; called by muse, mutect2, varscan2
- ATF7IP | c.2562T>A p.S854R | Missense Mutation (SNP) | VAF 49/169 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.803); catalogued as rs775317636, COSV53773834; called by muse, mutect2, varscan2
- ATG2B | c.2288C>T p.S763F | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs750152325, COSV63424301; called by muse, mutect2, varscan2
- ATN1 | c.3216C>T p.A1072= | Splice Region (SNP) | VAF 16/105 reads (15%) | catalogued as COSV57547181; called by muse, mutect2, varscan2
- ATP10B | c.98C>T p.P33L | Missense Mutation (SNP) | VAF 25/96 reads (26%) | SIFT tolerated (0.25); PolyPhen benign (0.015); catalogued as rs1561755209, COSV58779709; called by muse, mutect2, varscan2
- ATP13A4 | c.869G>T p.G290V | Missense Mutation (SNP) | VAF 44/188 reads (23%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.987); catalogued as COSV55069430, COSV99795101; called by muse, mutect2, varscan2
- ATP2B2 | c.2297G>A p.R766Q (on ENST00000352432; = p.R732Q on NM_001683.5) | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.991); catalogued as rs761076118, COSV59498409; called by muse, mutect2, varscan2
- ATP2C1 | c.2183C>T p.P728L | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60759109; called by muse, mutect2, varscan2
- ATRX | c.3875C>T p.S1292L | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); catalogued as COSV64879804; called by muse, mutect2, varscan2
- BRAP | c.595C>T p.P199S | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.927); catalogued as COSV59537498; called by muse, mutect2, varscan2
- BRD3 | c.971C>T p.S324F | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57704956; called by muse, mutect2
- BRPF1 | c.1663C>T p.P555S | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1290977778, COSV57406416; called by muse, mutect2, varscan2
- C12orf56 | c.1270G>A p.E424K (on ENST00000543942 / NM_001170633.2; = p.E264K on NM_001099676.3) | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV61485568, COSV61488362; called by muse, mutect2, varscan2
- C2orf50 | c.22G>A p.G8R | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.585); catalogued as rs758781703, COSV67510557; called by muse, varscan2
- CACNA1C | c.1850C>T p.S617F | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1336672006, COSV59742817; called by muse, mutect2, varscan2
- CACNA2D3 | c.1355G>A p.W452* | Nonsense Mutation (SNP) | VAF 15/86 reads (17%) | catalogued as COSV55558244; called by muse, mutect2, varscan2
- CALCRL | c.397G>A p.E133K | Missense Mutation (SNP) | VAF 27/88 reads (31%) | SIFT tolerated (0.05); PolyPhen benign (0.048); catalogued as rs369171869; called by muse, mutect2, varscan2
- CALML5 | c.136G>A p.E46K | Missense Mutation (SNP) | VAF 31/114 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as COSV66702641; called by muse, mutect2, varscan2
- CAPRIN2 | c.2524C>T p.P842S | Missense Mutation (SNP) | VAF 7/71 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.077); catalogued as COSV51833886; called by muse, mutect2
- CASKIN1 | c.2371C>T p.L791F | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated (0.5); PolyPhen benign (0.416); catalogued as COSV58216415; called by muse, mutect2
- CASKIN2 | c.724G>C p.E242Q | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0.145); catalogued as COSV58691880; called by muse, mutect2, varscan2
- CBL | c.2446G>A p.G816S | Missense Mutation (SNP) | VAF 16/100 reads (16%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.005); catalogued as COSV50646672; called by muse, mutect2, varscan2
- CC2D1A | c.1786C>T p.Q596* | Nonsense Mutation (SNP) | VAF 32/125 reads (26%) | catalogued as rs1236377215, COSV58784725; called by muse, mutect2, varscan2
- CCDC102B | c.1004C>T p.S335F | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT tolerated (0.26); PolyPhen benign (0.245); catalogued as COSV60147631; called by muse, mutect2, varscan2
- CCDC90B | c.202C>T p.Q68* | Nonsense Mutation (SNP) | VAF 20/72 reads (28%) | catalogued as COSV52624537; called by muse, mutect2, varscan2
- CCN1 | c.1102C>T p.P368S | Missense Mutation (SNP) | VAF 13/78 reads (17%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.454); catalogued as COSV71704389; called by muse, mutect2, varscan2
- CCR4 | c.341C>T p.S114F | Missense Mutation (SNP) | VAF 48/239 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as COSV58382969; called by muse, mutect2, varscan2
- CD163 | c.2116C>T p.P706S | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV63134925; called by muse, mutect2, varscan2
- CD209 | c.774G>A p.W258* | Nonsense Mutation (SNP) | VAF 19/103 reads (18%) | catalogued as rs1179420066, COSV99214305; called by muse, mutect2, varscan2
- CD209 | c.773G>A p.W258* | Nonsense Mutation (SNP) | VAF 20/105 reads (19%) | catalogued as COSV99214309; called by muse, mutect2, varscan2
- CD248 | c.712G>C p.D238H | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.62); catalogued as COSV60937148; called by muse, mutect2, varscan2
- CD300C | c.419C>T p.S140F | Missense Mutation (SNP) | VAF 25/115 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.812); catalogued as rs936303908, COSV58170266; called by muse, mutect2, varscan2
- CD38 | c.733G>A p.G245S | Missense Mutation (SNP) | VAF 27/150 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV56891641; called by muse, mutect2, varscan2
- CD93 | c.557G>A p.G186D | Missense Mutation (SNP) | VAF 21/112 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55666867; called by muse, mutect2, varscan2
- CDCP1 | c.502G>A p.D168N | Missense Mutation (SNP) | VAF 24/154 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0.034); catalogued as rs754445889, COSV56103795; called by muse, mutect2, varscan2
- CDH12 | c.23C>T p.S8F | Missense Mutation (SNP) | VAF 16/133 reads (12%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as rs1211476604, COSV66420319, COSV66423634; called by muse, mutect2
- CDH17 | c.578G>A p.R193Q | Missense Mutation (SNP) | VAF 39/180 reads (22%) | SIFT tolerated (0.48); PolyPhen benign (0.007); catalogued as rs377593984; called by muse, mutect2, varscan2
- CDK11B | c.1766C>T p.S589F | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1364199097, COSV58339727; called by muse, mutect2, varscan2
- CEP128 | c.191G>A p.R64Q | Missense Mutation (SNP) | VAF 18/86 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs201719117; called by muse, mutect2, varscan2
- CEP55 | c.1147G>A p.E383K | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV65185437; called by muse, mutect2, varscan2
- CEP85 | c.710G>A p.R237Q | Missense Mutation (SNP) | VAF 9/87 reads (10%) | SIFT tolerated (0.72); PolyPhen benign (0.034); catalogued as rs779280111, COSV53330615; called by muse, mutect2
- CES4A | c.983C>T p.P328L | Missense Mutation (SNP) | VAF 41/175 reads (23%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.612); catalogued as COSV58654261; called by muse, mutect2, varscan2
- CHAF1A | c.2570C>T p.P857L | Missense Mutation (SNP) | VAF 16/85 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.132); catalogued as rs1354681480, COSV56674406; called by muse, mutect2, varscan2
- CHRD | c.769G>A p.A257T | Missense Mutation (SNP) | VAF 83/317 reads (26%) | SIFT tolerated (0.57); PolyPhen benign (0.383); catalogued as COSV52610051; called by muse, mutect2, varscan2
- CHRND | c.331C>T p.P111S | Missense Mutation (SNP) | VAF 13/92 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV99286073; called by muse, mutect2, varscan2
- CIAO2A | c.164C>T p.T55I | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as COSV55538819; called by muse, mutect2
- CIRBP | c.55G>A p.E19K | Missense Mutation (SNP) | VAF 65/279 reads (23%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.781); catalogued as COSV58011575; called by muse, mutect2, varscan2
- CLEC4E | c.214G>A p.G72R | Missense Mutation (SNP) | VAF 39/125 reads (31%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.546); catalogued as COSV100222741, COSV55226531; called by muse, mutect2, varscan2
- CNTN5 | c.1744G>A p.E582K | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); catalogued as rs778080661, COSV54289360, COSV54331213; called by muse, mutect2
- CNTNAP2 | c.1085G>A p.G362E | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.227); catalogued as COSV62144663, COSV62167074; called by muse, mutect2, varscan2
- CNTNAP4 | c.2044T>C p.Y682H | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.845); catalogued as COSV56690330; called by muse, mutect2
- COL14A1 | c.4927C>T p.P1643S | Missense Mutation (SNP) | VAF 25/114 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.511); catalogued as COSV52860843; called by muse, mutect2, varscan2
- COL14A1 | c.5117T>C p.V1706A | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV52860853; called by muse, mutect2
- COL1A1 | c.2777G>A p.G926D | Missense Mutation (SNP) | VAF 21/141 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99867938; called by muse, mutect2, varscan2
- COL1A1 | c.2776G>A p.G926S | Missense Mutation (SNP) | VAF 21/139 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM870006, COSV99867940; called by muse, mutect2, varscan2
- COL1A2 | c.760C>T p.P254S | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0.07); catalogued as rs1373578009, COSV51961706; called by muse, mutect2, varscan2
- COL4A1 | c.1897+1G>A p.X633_splice | Splice Site (SNP) | VAF 47/209 reads (22%) | catalogued as COSV101011444; called by muse, mutect2, varscan2
- COL4A1 | c.1897G>A p.G633S | Missense Mutation (SNP) | VAF 48/212 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV101010967, COSV65422992; called by muse, mutect2, varscan2
- COL8A2 | c.962C>T p.P321L | Missense Mutation (SNP) | VAF 3/37 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.099); catalogued as COSV57442535; called by muse, mutect2
- CR2 | c.682G>A p.E228K | Missense Mutation (SNP) | VAF 35/94 reads (37%) | SIFT tolerated (0.86); PolyPhen benign (0.034); catalogued as COSV65508616; called by muse, mutect2, varscan2
- CRAMP1 | c.2425C>T p.P809S | Missense Mutation (SNP) | VAF 35/173 reads (20%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.601); catalogued as rs1375430585, COSV51964085; called by muse, mutect2, varscan2
- CRB1 | c.2533G>A p.G845S | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.321); catalogued as COSV66331697; called by muse, mutect2, varscan2
- CRB2 | c.472G>A p.G158R | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs746741771, COSV63502833; called by muse, mutect2, varscan2
- CSF2RB | c.2194C>T p.P732S | Missense Mutation (SNP) | VAF 25/114 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.079); catalogued as COSV53259178; called by muse, mutect2, varscan2
- CUBN | c.992C>T p.S331F | Missense Mutation (SNP) | VAF 36/129 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV104428219, COSV64720787; called by muse, mutect2, varscan2
- CUZD1 | c.224C>T p.S75F | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV59028923; called by muse, mutect2
- CWC22 | c.1612C>T p.R538C | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs771674660, COSV55430299; called by muse, mutect2
- CWC22 | c.406C>G p.P136A | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55430314; called by muse, mutect2, varscan2
- CWH43 | c.373G>A p.G125R | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs765329114, COSV56941071; called by muse, mutect2, varscan2
- CXorf66 | c.42A>T p.K14N | Missense Mutation (SNP) | VAF 26/63 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV65169499; called by muse, mutect2, varscan2
- CYP2C18 | c.1402G>A p.D468N | Missense Mutation (SNP) | VAF 44/148 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.021); catalogued as COSV53673548; called by muse, mutect2, varscan2
- CYP4X1 | c.1366G>A p.G456R | Missense Mutation (SNP) | VAF 34/137 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64151213; called by muse, mutect2, varscan2
- CYTIP | c.167G>A p.R56Q | Missense Mutation (SNP) | VAF 21/103 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.054); catalogued as rs752496759, COSV51632203; called by muse, mutect2, varscan2
- DAPP1 | c.768G>A p.W256* | Nonsense Mutation (SNP) | VAF 6/29 reads (21%) | catalogued as COSV56450546, COSV56451446; called by muse, mutect2, varscan2
- DBX2 | c.647G>A p.R216Q | Missense Mutation (SNP) | VAF 56/275 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs375287819, COSV60339154; called by muse, mutect2, varscan2
- DDX42 | c.640G>A p.E214K | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.581); catalogued as COSV63790665; called by muse, mutect2, varscan2
- DEFB113 | c.115C>T p.R39C | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.947); catalogued as rs1209328851, COSV59038214; called by muse, mutect2, varscan2
- DGKE | c.656C>T p.P219L | Missense Mutation (SNP) | VAF 12/79 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52350527; called by muse, mutect2, varscan2
- DHCR7 | c.648T>A p.F216L | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT tolerated (0.52); PolyPhen benign (0.003); catalogued as COSV62795155, COSV62795902; called by muse, mutect2, varscan2
- DHRSX | c.905C>T p.S302F | Missense Mutation (SNP) | VAF 25/106 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.813); catalogued as COSV58136169; called by muse, mutect2, varscan2
- DHX36 | c.883C>T p.R295C | Missense Mutation (SNP) | VAF 29/86 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57672487; called by muse, mutect2, varscan2
- DISP1 | c.3431C>T p.P1144L | Missense Mutation (SNP) | VAF 47/128 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.028); catalogued as COSV52656631; called by muse, mutect2, varscan2
- DMP1 | c.34G>A p.G12R | Missense Mutation (SNP) | VAF 24/157 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV56820915; called by muse, mutect2, varscan2
- DMP1 | c.1336G>A p.E446K | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.867); catalogued as COSV56818628; called by muse, mutect2, varscan2
- DMTN | c.1115C>T p.S372F | Missense Mutation (SNP) | VAF 19/98 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56113448; called by muse, mutect2, varscan2
- DNAH10 | c.7943C>T p.S2648L (on ENST00000409039; = p.S2587L on NM_207437.3) | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs751315749, COSV68987215; called by muse, mutect2, varscan2
- DNAH2 | c.12995G>A p.R4332Q | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.206); catalogued as COSV66717097, COSV66722370; called by muse, mutect2, varscan2
- DNAH3 | c.4672G>A p.D1558N | Missense Mutation (SNP) | VAF 28/108 reads (26%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.999); catalogued as COSV54534668; called by muse, mutect2, varscan2
- DNAH7 | c.7324C>T p.R2442C | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs376122638, COSV56773131, COSV56774226; called by muse, mutect2, varscan2
- DNAH8 | c.3160C>T p.P1054S | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT tolerated (0.57); PolyPhen benign (0.001); catalogued as COSV59463094; called by muse, mutect2, varscan2
- DNM2 | c.782C>T p.S261F | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV58966710; called by mutect2, varscan2
- DOCK2 | c.550T>C p.F184L | Missense Mutation (SNP) | VAF 40/149 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); catalogued as COSV56971502; called by muse, mutect2, varscan2
- DOCK2 | c.1295A>G p.Q432R | Missense Mutation (SNP) | VAF 22/93 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.024); catalogued as COSV56971513; called by muse, mutect2, varscan2
- DOCK5 | c.5288G>A p.R1763K | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.931); catalogued as rs751118173, COSV52406218; called by muse, mutect2, varscan2
- DOK5 | c.520G>A p.V174I | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.006); catalogued as rs1416702061, COSV52822589; called by muse, mutect2, varscan2
- DOK6 | c.512A>T p.N171I | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101234871; called by muse, mutect2, varscan2
- DOK6 | c.513T>A p.N171K | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.762); catalogued as COSV101234873; called by muse, mutect2, varscan2
- DOK6 | c.838G>A p.E280K | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.271); catalogued as COSV66934140; called by muse, mutect2, varscan2
- DOP1B | c.3035C>T p.S1012F | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); catalogued as COSV67692426; called by muse, varscan2
- DPP9 | c.1940C>T p.P647L (on ENST00000598800; = p.P676L on NM_139159.5) | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53592705, COSV99506098; called by muse, mutect2, varscan2
- DPYSL4 | c.811+1G>A p.X271_splice | Splice Site (SNP) | VAF 21/68 reads (31%) | catalogued as COSV58308475; called by muse, mutect2, varscan2
- DRD3 | c.547A>C p.I183L | Missense Mutation (SNP) | VAF 20/96 reads (21%) | SIFT tolerated (0.17); PolyPhen benign (0.413); catalogued as COSV55681514; called by muse, varscan2
- DSCAM | c.2416G>A p.E806K | Missense Mutation (SNP) | VAF 26/108 reads (24%) | SIFT tolerated (0.23); PolyPhen benign (0.01); catalogued as COSV68021299; called by muse, mutect2, varscan2
- DUSP12 | c.547C>T p.R183C | Missense Mutation (SNP) | VAF 25/85 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs778635807, COSV63411293, COSV63411708; called by muse, mutect2, varscan2
- DUSP26 | c.211C>T p.L71F | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV56361792; called by muse, mutect2
- DYRK2 | c.1445C>T p.S482F (on ENST00000344096 / NM_006482.3; = p.S409F on NM_003583.4) | Missense Mutation (SNP) | VAF 28/109 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV59846869; called by muse, mutect2, varscan2
- DYTN | c.226G>A p.E76K | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.045); catalogued as COSV71751604; called by muse, mutect2
- ELANE | c.538C>G p.L180V | Missense Mutation (SNP) | VAF 31/163 reads (19%) | SIFT tolerated (0.25); PolyPhen benign (0.149); catalogued as rs201977478, COSV55048567, COSV55049714; called by muse, mutect2, varscan2
- ELP4 | c.773T>C p.I258T (on ENST00000350638; = p.I257T on NM_019040.5) | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV63355244; called by muse, mutect2, varscan2
- ENDOV | c.811C>T p.P271S | Missense Mutation (SNP) | VAF 13/86 reads (15%) | SIFT tolerated, low confidence (0.11); PolyPhen probably damaging (0.994); catalogued as COSV60498474; called by muse, mutect2, varscan2
- EPHA6 | c.1478C>A p.S493Y | Missense Mutation (SNP) | VAF 25/78 reads (32%) | SIFT tolerated (0.45); PolyPhen probably damaging (0.997); catalogued as COSV67560131, COSV67560379; called by muse, mutect2, varscan2
- EPHB2 | c.2060G>A p.G687D (on ENST00000400191 / NM_001309193.2; = p.G688D on NM_004442.7) | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65864062; called by muse, mutect2, varscan2
- EPHB3 | c.2359C>T p.P787S | Missense Mutation (SNP) | VAF 23/111 reads (21%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as COSV57807458; called by muse, mutect2, varscan2
- ERBB4 | c.2221G>A p.G741R | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV53532933; called by muse, mutect2, varscan2
- EVI5 | c.2219C>T p.S740F | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.974); catalogued as COSV64827476, COSV64827524; called by muse, mutect2, varscan2
- EVPL | c.3835G>A p.E1279K | Missense Mutation (SNP) | VAF 37/142 reads (26%) | SIFT tolerated (0.14); PolyPhen benign (0.158); catalogued as rs776275065, COSV56913299; called by muse, mutect2, varscan2
- EXOC3 | c.520C>T p.H174Y | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT tolerated (0.37); PolyPhen benign (0.007); catalogued as COSV59267695; called by muse, mutect2, varscan2
- F2 | c.491C>T p.T164I | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT tolerated (0.3); PolyPhen benign (0.01); catalogued as COSV61316519, COSV61318086; called by muse, mutect2, varscan2
- F8 | c.2449C>G p.P817A | Missense Mutation (SNP) | VAF 31/74 reads (42%) | SIFT tolerated (0.11); PolyPhen benign (0.158); catalogued as COSV64275981; called by muse, mutect2, varscan2
- FAM131C | c.267G>A p.V89= | Splice Region (SNP) | VAF 12/54 reads (22%) | catalogued as COSV100989731, COSV65153821; called by muse, mutect2, varscan2
- FAM170A | c.854G>A p.G285E | Missense Mutation (SNP) | VAF 27/120 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1427313521, COSV58926105; called by muse, mutect2, varscan2
- FAM71F1 | c.175C>T p.L59F | Missense Mutation (SNP) | VAF 33/106 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV59374278; called by muse, mutect2, varscan2
- FAM9B | c.148G>A p.G50R | Missense Mutation (SNP) | VAF 45/131 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV59119935; called by muse, mutect2, varscan2
- FANCA | c.767C>T p.T256I | Missense Mutation (SNP) | VAF 21/134 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0.01); catalogued as COSV66882565; called by muse, mutect2, varscan2
- FAT3 | c.7465G>A p.A2489T | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.969); catalogued as COSV53141062; called by muse, mutect2, varscan2
- FAT3 | c.10439C>T p.P3480L | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV53141100, COSV99035558; called by muse, mutect2, varscan2
- FBLN7 | c.965C>T p.P322L | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55616666; called by muse, mutect2, varscan2
- FBN3 | c.1879G>A p.G627S | Missense Mutation (SNP) | VAF 18/85 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV54463316; called by muse, mutect2, varscan2
- FCGR3B | c.521G>A p.G174E | Missense Mutation (SNP) | VAF 39/123 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54209568; called by muse, mutect2, varscan2
- FCRL2 | c.1211G>A p.G404E | Missense Mutation (SNP) | VAF 14/95 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.029); catalogued as COSV63834280; called by muse, varscan2
- FGA | c.1268G>A p.G423E | Missense Mutation (SNP) | VAF 42/248 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.946); catalogued as COSV57398197; called by muse, mutect2, varscan2
- FGFR4 | c.1301G>A p.R434Q | Missense Mutation (SNP) | VAF 36/188 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs766706277, COSV52801567, COSV52803164; called by muse, mutect2, varscan2
- FHDC1 | c.1805C>T p.P602L | Missense Mutation (SNP) | VAF 45/243 reads (19%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as COSV52601389; called by muse, mutect2, varscan2
- FLG2 | c.4784G>A p.R1595Q | Missense Mutation (SNP) | VAF 94/299 reads (31%) | SIFT tolerated (0.59); catalogued as rs201802558, COSV101165639, COSV66167043; called by muse, mutect2, varscan2
- FLT3 | c.1789T>A p.Y597N | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.046); catalogued as COSV54060876; called by muse, mutect2, varscan2
- FMN2 | c.1408C>T p.R470W | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.798); catalogued as rs997168836, COSV60418289; called by muse, varscan2
- FMNL3 | c.1402C>T p.R468* | Nonsense Mutation (SNP) | VAF 4/22 reads (18%) | catalogued as rs1042244326, COSV99525414; called by muse, mutect2
- FMO5 | c.1383A>C p.L461F | Missense Mutation (SNP) | VAF 15/78 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as COSV54208557; called by muse, varscan2
- FNIP2 | c.2543C>T p.P848L | Missense Mutation (SNP) | VAF 29/106 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV52442499; called by muse, mutect2, varscan2
- FRMD4B | c.1172T>A p.L391Q | Missense Mutation (SNP) | VAF 45/219 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.063); catalogued as COSV68331549; called by muse, mutect2, varscan2
- FRYL | c.6428A>G p.N2143S | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.932); catalogued as rs1280081850, COSV51953402; called by muse, mutect2
- FSTL5 | c.2334G>A p.M778I | Missense Mutation (SNP) | VAF 34/146 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.009); catalogued as COSV60209996; called by muse, mutect2, varscan2
- FSTL5 | c.1568G>A p.R523K | Missense Mutation (SNP) | VAF 21/102 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as COSV60210002; called by muse, mutect2, varscan2
- FSTL5 | c.835C>T p.P279S | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.419); catalogued as COSV60210008; called by muse, mutect2, varscan2
- FUT3 | c.698C>T p.T233I | Missense Mutation (SNP) | VAF 24/120 reads (20%) | SIFT tolerated (0.16); PolyPhen benign (0.125); catalogued as COSV54606983, COSV99744281; called by muse, mutect2, varscan2
- GAB4 | c.420G>A p.M140I | Missense Mutation (SNP) | VAF 60/327 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs867433638, COSV68752963; called by muse, mutect2, varscan2
- GALNT14 | c.895G>A p.D299N | Missense Mutation (SNP) | VAF 19/122 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV61103968; called by muse, mutect2, varscan2
- GAREM1 | c.956C>T p.P319L | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT tolerated (0.79); PolyPhen benign (0.007); catalogued as COSV52515781; called by muse, mutect2, varscan2
- GARRE1 | c.961G>A p.E321K | Missense Mutation (SNP) | VAF 32/192 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV55101344; called by muse, mutect2, varscan2
- GART | c.1883G>A p.R628K | Missense Mutation (SNP) | VAF 25/121 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as COSV67819091; called by muse, mutect2, varscan2
- GCKR | c.1582G>A p.G528R | Missense Mutation (SNP) | VAF 16/90 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as COSV53109404; called by muse, mutect2, varscan2
- GGA3 | c.499C>T p.P167S (on ENST00000537686 / NM_138619.4; = p.P134S on NM_014001.5) | Missense Mutation (SNP) | VAF 27/131 reads (21%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.958); catalogued as rs1448359663, COSV55457648; called by muse, mutect2, varscan2
- GIMAP7 | c.842G>A p.W281* | Nonsense Mutation (SNP) | VAF 16/56 reads (29%) | catalogued as COSV57959906; called by muse, mutect2, varscan2
- GJB4 | c.544G>A p.E182K | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs267598569, COSV58356608; called by muse, mutect2, varscan2
- GLI1 | c.3191C>T p.S1064F | Missense Mutation (SNP) | VAF 41/209 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.172); catalogued as rs770128594, COSV57364561; called by muse, mutect2, varscan2
- GMIP | c.826C>T p.R276C | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.842); catalogued as rs750327461, COSV52558036; called by muse, mutect2
- GPIHBP1 | c.451G>A p.G151S | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.385); catalogued as COSV58209132, COSV58209431; called by muse, mutect2, varscan2
- GPR139 | c.322G>A p.E108K | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV58503758; called by muse, mutect2, varscan2
- GPR26 | c.103G>A p.D35N | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.725); catalogued as rs758080988, COSV52934942, COSV99501044; called by muse, mutect2, varscan2
- GPX5 | c.478T>A p.S160T | Missense Mutation (SNP) | VAF 42/221 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.01); catalogued as COSV69079697; called by muse, mutect2, varscan2
- GRIN3A | c.2482G>A p.G828R | Missense Mutation (SNP) | VAF 20/40 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs866984142, COSV62456022; called by muse, mutect2, varscan2
- GRIN3A | c.2060T>A p.I687N | Missense Mutation (SNP) | VAF 32/108 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV62456028; called by muse, mutect2, varscan2
- GRK3 | c.860G>A p.G287D | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV60798246; called by muse, mutect2, varscan2
- GTF2IRD1 | c.802C>T p.R268* | Nonsense Mutation (SNP) | VAF 15/70 reads (21%) | catalogued as rs782284512, COSV56085814; called by muse, mutect2, varscan2
- GTPBP6 | c.1091C>T p.S364F | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs763730404, COSV58205342; called by muse, mutect2, varscan2
- GUSB | c.1160C>T p.P387L | Missense Mutation (SNP) | VAF 20/121 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59222651; called by muse, mutect2, varscan2
- HBD | c.142G>A p.D48N | Missense Mutation (SNP) | VAF 28/115 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as COSV53082140, COSV99496475; called by muse, mutect2, varscan2
- HCN4 | c.1187G>A p.R396Q | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56085178; called by muse, mutect2, varscan2
- HEATR1 | c.304T>G p.S102A | Missense Mutation (SNP) | VAF 32/102 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.519); catalogued as COSV63979484; called by muse, mutect2, varscan2
- HGFAC | c.1960C>T p.P654S | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.055); catalogued as COSV66977103; called by muse, mutect2, varscan2
- HIPK4 | c.698T>C p.L233P | Missense Mutation (SNP) | VAF 23/98 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.156); catalogued as COSV52523106; called by muse, mutect2, varscan2
- HK2 | c.518A>T p.K173M | Missense Mutation (SNP) | VAF 36/160 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99309452; called by muse, mutect2, varscan2
- HNF4G | c.263G>A p.R88K (on ENST00000354370 / NM_001330561.2; = p.R135K on NM_004133.5) | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.299); catalogued as COSV100584375, COSV62970975; called by muse, mutect2, varscan2
- HOXA1 | c.4G>A p.D2N | Missense Mutation (SNP) | VAF 64/187 reads (34%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); catalogued as COSV56067132; called by muse, mutect2, varscan2
- HPS3 | c.1399C>T p.L467F | Missense Mutation (SNP) | VAF 24/100 reads (24%) | SIFT tolerated (0.05); PolyPhen benign (0.377); catalogued as COSV56055779; called by muse, mutect2, varscan2
- HRNR | c.6019G>A p.G2007R | Missense Mutation (SNP) | VAF 106/1338 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.142); catalogued as COSV64260268; called by muse, mutect2
- HRNR | c.1438C>T p.Q480* | Nonsense Mutation (SNP) | VAF 64/376 reads (17%) | catalogued as COSV64260272; called by muse, mutect2
- HRNR | c.1436C>T p.T479I | Missense Mutation (SNP) | VAF 68/372 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs139476726, COSV64260276; called by muse, mutect2
- HTR1D | c.1068C>A p.Y356* | Nonsense Mutation (SNP) | VAF 30/133 reads (23%) | catalogued as COSV58448588; called by muse, mutect2, varscan2
- HTR5A | c.23C>T p.T8I | Missense Mutation (SNP) | VAF 72/220 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.07); catalogued as COSV55284174; called by muse, mutect2
- HYDIN | c.2008G>A p.E670K | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.285); catalogued as rs866201822, COSV55478832; called by muse, mutect2, varscan2
- IDO2 | c.904C>T p.P302S (on ENST00000389060; = p.P315S on NM_194294.2) | Missense Mutation (SNP) | VAF 13/78 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.99); catalogued as rs746234998, COSV58425563; called by muse, mutect2, varscan2
- IGF1R | c.2932C>T p.P978S | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV99158604; called by muse, mutect2
- IGF1R | c.2933C>T p.P978L | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1555463013, COSV99158638; ClinVar: uncertain significance; called by muse, mutect2
- IGHV1-2 | c.325G>A p.D109N | Missense Mutation (SNP) | VAF 68/278 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs200903159; called by muse, mutect2, varscan2
- IGHV1-69 | c.119C>T p.S40F | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.705); catalogued as rs1555593985; called by mutect2, varscan2
- IGHV3-7 | c.133G>A p.G45R | Missense Mutation (SNP) | VAF 40/169 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.246); catalogued as rs540690441; called by muse, mutect2, varscan2
- IL1F10 | c.10C>T p.L4F | Missense Mutation (SNP) | VAF 3/21 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV61750795; called by muse, mutect2
- IL27RA | c.1034C>T p.P345L | Missense Mutation (SNP) | VAF 45/203 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.138); catalogued as COSV54601868; called by muse, mutect2, varscan2
- IL2RB | c.1205G>A p.G402E | Missense Mutation (SNP) | VAF 28/105 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.278); catalogued as COSV53427458; called by muse, mutect2, varscan2
- INHBA | c.559G>A p.D187N | Missense Mutation (SNP) | VAF 29/102 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.102); catalogued as COSV54223001, COSV54224010; called by muse, mutect2, varscan2
- IQCF2 | c.19-1G>A p.X7_splice | Splice Site (SNP) | VAF 10/48 reads (21%) | catalogued as COSV60761356; called by muse, mutect2, varscan2
- IQCN | c.244C>T p.L82F | Missense Mutation (SNP) | VAF 27/123 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as rs774629439, COSV66575603; called by muse, mutect2, varscan2
- ITGA5 | c.674G>A p.G225E | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53219305; called by muse, mutect2, varscan2
- ITGAL | c.263C>T p.S88F | Missense Mutation (SNP) | VAF 20/97 reads (21%) | SIFT tolerated (0.17); PolyPhen benign (0.014); catalogued as COSV63321908; called by muse, mutect2, varscan2
- ITPR1 | c.7762G>T p.V2588F (on ENST00000354582; = p.V2533F on NM_002222.7) | Missense Mutation (SNP) | VAF 24/103 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56991739, COSV56999481; called by muse, mutect2, varscan2
- JADE1 | c.80C>T p.S27F | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs774236013, COSV56903821; called by muse, mutect2, varscan2
- JAZF1 | c.380C>T p.P127L | Missense Mutation (SNP) | VAF 3/27 reads (11%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.995); catalogued as rs1265343481, COSV52241098; called by muse, mutect2
- KBTBD3 | c.721G>A p.V241M | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); catalogued as COSV73241520; called by muse, mutect2, varscan2
- KCNA10 | c.1079G>A p.G360E | Missense Mutation (SNP) | VAF 30/133 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100871480; called by muse, mutect2, varscan2
- KCNA10 | c.1078G>A p.G360R | Missense Mutation (SNP) | VAF 30/134 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100871449; called by muse, mutect2, varscan2
- KCNH1 | c.2411C>T p.S804F (on ENST00000271751 / NM_172362.3; = p.S777F on NM_002238.4) | Missense Mutation (SNP) | VAF 15/135 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.133); catalogued as COSV55090748; called by mutect2, varscan2
- KCNH5 | c.823G>A p.G275R | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59767091; called by muse, mutect2, varscan2
- KCNMB1 | c.263C>T p.A88V | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT tolerated (0.89); PolyPhen benign (0.023); catalogued as COSV51133580; called by muse, mutect2, varscan2
- KCNQ5 | c.1584G>A p.M528I | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.579); catalogued as COSV59670624; called by muse, mutect2, varscan2
- KDM4A | c.551C>T p.S184F | Missense Mutation (SNP) | VAF 28/156 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64960100; called by muse, mutect2, varscan2
- KEL | c.878G>A p.R293Q | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs142497392, COSV100787190; called by muse, mutect2, varscan2
- KIF15 | c.1462C>T p.R488C | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.862); catalogued as rs369789303; called by muse, mutect2, varscan2
- KIF21B | c.4094C>T p.S1365F (on ENST00000422435 / NM_001252100.2; = p.S1352F on NM_017596.4) | Missense Mutation (SNP) | VAF 40/258 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.745); catalogued as COSV59758236; called by muse, varscan2
- KIF2B | c.505G>A p.E169K | Missense Mutation (SNP) | VAF 26/125 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.115); catalogued as COSV52131446; called by muse, mutect2, varscan2
- KIF4B | c.1207A>G p.S403G | Missense Mutation (SNP) | VAF 39/173 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.046); catalogued as COSV70530353; called by muse, mutect2, varscan2
- KLHDC4 | c.1543G>A p.E515K | Missense Mutation (SNP) | VAF 15/87 reads (17%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.04); catalogued as COSV54509733; called by muse, mutect2, varscan2
- KLRG1 | c.422G>A p.W141* | Nonsense Mutation (SNP) | VAF 9/46 reads (20%) | catalogued as COSV99868541; called by muse, mutect2, varscan2
- KPNA6 | c.1447C>A p.Q483K | Missense Mutation (SNP) | VAF 18/85 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV65359616, COSV65361057; called by muse, mutect2, varscan2
- KRT25 | c.337G>A p.G113S | Missense Mutation (SNP) | VAF 27/134 reads (20%) | SIFT tolerated (0.3); PolyPhen benign (0.043); catalogued as COSV56445692; called by muse, mutect2, varscan2
- KRT36 | c.1258C>T p.P420S | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT tolerated (0.31); PolyPhen benign (0.006); catalogued as COSV60203450; called by muse, mutect2, varscan2
- KRT71 | c.293C>T p.P98L | Missense Mutation (SNP) | VAF 16/89 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.053); catalogued as COSV57291828; called by muse, mutect2, varscan2
- KRTAP13-1 | c.416C>T p.S139F | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.199); catalogued as COSV62663807; called by muse, mutect2, varscan2
- LARGE2 | c.1499C>T p.P500L | Missense Mutation (SNP) | VAF 26/145 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57654183; called by muse, mutect2, varscan2
- LARP4B | c.1564C>T p.P522S | Missense Mutation (SNP) | VAF 24/97 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); catalogued as COSV60222337; called by muse, mutect2, varscan2
- LENG9 | c.601C>T p.Q201* | Nonsense Mutation (SNP) | VAF 25/62 reads (40%) | catalogued as COSV100002905; called by muse, mutect2, varscan2
- LEPR | c.2552C>T p.S851F | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0.14); catalogued as rs1201055245, COSV60758991; called by muse, mutect2, varscan2
- LGMN | c.230C>T p.S77F | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as COSV58403312; called by muse, mutect2, varscan2
- LHFPL2 | c.205C>T p.R69W | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.005); catalogued as rs372556856; called by muse, mutect2, varscan2
- LILRB3 | c.1558G>C p.V520L (on ENST00000346401; = p.V508L on NM_006864.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/115 reads (11%) | SIFT tolerated (0.21); PolyPhen benign (0.031); catalogued as COSV54440215; called by muse, mutect2, varscan2
- LNX2 | c.1880C>T p.P627L | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.641); catalogued as COSV60336977; called by muse, mutect2, varscan2
- LONP2 | c.700C>T p.P234S | Missense Mutation (SNP) | VAF 27/115 reads (23%) | SIFT tolerated (0.73); PolyPhen benign (0.003); catalogued as COSV53524026; called by muse, mutect2, varscan2
- LPAR4 | c.433C>T p.R145* | Nonsense Mutation (SNP) | VAF 19/56 reads (34%) | catalogued as rs1407911813, COSV70912324; called by muse, mutect2, varscan2
- LPIN2 | c.1713G>T p.L571= | Splice Region (SNP) | VAF 7/27 reads (26%) | catalogued as COSV55241692; called by muse, mutect2, varscan2
- LRP2 | c.8353G>A p.E2785K | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55562148; called by muse, mutect2, varscan2
- LRRC31 | c.554G>A p.G185E | Missense Mutation (SNP) | VAF 20/108 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52980583, COSV52981736; called by muse, mutect2, varscan2
- LRTM1 | c.658G>A p.D220N | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0.05); PolyPhen benign (0.018); catalogued as COSV55558253; called by muse, mutect2, varscan2
- LYPD3 | c.727C>T p.P243S | Missense Mutation (SNP) | VAF 129/266 reads (48%) | SIFT tolerated (0.13); PolyPhen benign (0.018); catalogued as COSV54989151; called by muse, mutect2, varscan2
- MAB21L3 | c.239C>T p.A80V | Missense Mutation (SNP) | VAF 12/110 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.045); catalogued as rs141687184; called by muse, mutect2, varscan2
- MAGEB6 | c.1024G>A p.V342M | Missense Mutation (SNP) | VAF 45/119 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.564); catalogued as COSV66872611; called by muse, mutect2, varscan2
- MAGEE1 | c.1733G>A p.G578E | Missense Mutation (SNP) | VAF 12/20 reads (60%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); catalogued as COSV63911097; called by muse, mutect2, varscan2
- MAML1 | c.2087C>T p.P696L | Missense Mutation (SNP) | VAF 42/190 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.114); catalogued as COSV52987190; called by muse, mutect2, varscan2
- MAP2K1 | c.740G>A p.W247* | Nonsense Mutation (SNP) | VAF 54/214 reads (25%) | catalogued as COSV61072140; called by muse, mutect2, varscan2
- MAP3K10 | c.1498G>A p.G500R | Missense Mutation (SNP) | VAF 28/143 reads (20%) | SIFT tolerated (0.36); PolyPhen benign (0.039); catalogued as COSV53423697; called by muse, mutect2, varscan2
- MAP3K3 | c.929C>T p.P310L | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.411); catalogued as COSV62281186; called by muse, mutect2
- MARCO | c.577G>A p.G193R | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59055292, COSV59059028; called by muse, mutect2, varscan2
- MCM2 | c.1945C>T p.L649F | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs377424967, COSV54035108; called by muse, mutect2, varscan2
- MDM1 | c.1855C>T p.P619S | Missense Mutation (SNP) | VAF 23/107 reads (21%) | SIFT tolerated (0.37); PolyPhen benign (0.04); catalogued as COSV57447636, COSV57448676; called by muse, mutect2, varscan2
- MEFV | c.121C>T p.P41S | Missense Mutation (SNP) | VAF 25/105 reads (24%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as COSV54824516; called by muse, mutect2, varscan2
- METAP2 | c.1264C>T p.R422C | Missense Mutation (SNP) | VAF 18/113 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs754957570, COSV51565443; called by muse, mutect2, varscan2
- MFSD6 | c.1195G>A p.D399N | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs897396705, COSV55623827; called by muse, mutect2, varscan2
- MIB2 | c.1940G>A p.S647N | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (0.95); PolyPhen possibly damaging (0.758); catalogued as COSV61543006; called by muse, mutect2, varscan2
- MICALL2 | c.2051C>T p.P684L | Missense Mutation (SNP) | VAF 16/91 reads (18%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.994); catalogued as rs780996529, COSV52517044; called by muse, mutect2, varscan2
- MMP10 | c.961C>T p.P321S | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as rs778525609, COSV54246859, COSV99666814; called by muse, mutect2, varscan2
- MMRN1 | c.719G>A p.W240* | Nonsense Mutation (SNP) | VAF 7/40 reads (18%) | catalogued as rs953048852, COSV53338114; called by muse, mutect2, varscan2
- MNDA | c.1045G>A p.D349N | Missense Mutation (SNP) | VAF 61/153 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.511); catalogued as rs1196161846, COSV63741473; called by muse, mutect2, varscan2
- MOB3B | c.399A>C p.E133D | Missense Mutation (SNP) | VAF 19/79 reads (24%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as COSV51783714; called by muse, mutect2, varscan2
- MPHOSPH8 | c.607A>T p.I203F | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.23); catalogued as COSV64056391; called by mutect2, varscan2
- MRGPRX2 | c.140G>A p.G47E | Missense Mutation (SNP) | VAF 31/172 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.942); catalogued as COSV61674004; called by muse, mutect2, varscan2
- MRPL13 | c.23C>T p.P8L | Missense Mutation (SNP) | VAF 25/161 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.014); catalogued as COSV100012467; called by muse, mutect2, varscan2
- MRPL13 | c.22C>T p.P8S | Missense Mutation (SNP) | VAF 24/159 reads (15%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs1159805809, COSV59962162; called by muse, mutect2, varscan2
- MS4A10 | c.511G>C p.E171Q | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.592); catalogued as COSV57633115; called by muse, mutect2, varscan2
- MSMO1 | c.625C>T p.H209Y | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54970273; called by muse, mutect2, varscan2
- MSTN | c.1102G>A p.V368I | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as COSV53621554; called by muse, mutect2, varscan2
- MTIF2 | c.1793T>C p.I598T | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.795); catalogued as COSV55052604; called by muse, mutect2, varscan2
- MTOR | c.6620C>T p.T2207I | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.762); catalogued as COSV63874670; called by muse, mutect2, varscan2
- MUC16 | c.25454C>T p.P8485L | Missense Mutation (SNP) | VAF 48/275 reads (17%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.021); catalogued as rs1435778029, COSV67478873; called by muse, mutect2, varscan2
- MUC16 | c.19445C>T p.S6482L | Missense Mutation (SNP) | VAF 19/103 reads (18%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.048); catalogued as rs1252390472, COSV67478880; called by muse, mutect2, varscan2
- MUC16 | c.11045G>A p.R3682K | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.01); catalogued as rs746511672, COSV67478890; called by muse, mutect2, varscan2
- MUC16 | c.5824C>T p.P1942S | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.932); catalogued as COSV67478919; called by muse, mutect2, varscan2
- MUC16 | c.4214C>T p.S1405L | Missense Mutation (SNP) | VAF 19/92 reads (21%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.048); catalogued as COSV67453469; called by muse, mutect2, varscan2
- MUC5B | c.15306G>A p.M5102I | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.344); catalogued as rs754750652, COSV71594018; called by muse, mutect2, varscan2
- MUCL1 | c.115G>A p.D39N | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.1); catalogued as COSV58192504; called by muse, mutect2
- MVB12B | c.173C>T p.S58F | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV63259465; called by muse, mutect2, varscan2
- MYH15 | c.2573G>A p.G858E | Missense Mutation (SNP) | VAF 29/128 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as COSV56314551; called by muse, mutect2, varscan2
- MYH2 | c.2632G>A p.E878K | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.119); catalogued as rs745357669, COSV55431560; called by muse, mutect2, varscan2
- MYO1F | c.1648G>A p.G550R | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT tolerated (0.2); PolyPhen benign (0.094); catalogued as rs1220387531, COSV57797430; called by muse, mutect2, varscan2
- MYO5C | c.1771C>T p.Q591* | Nonsense Mutation (SNP) | VAF 19/87 reads (22%) | catalogued as rs267604255, COSV55904182; called by muse, mutect2, varscan2
- MYO7B | c.1534G>A p.E512K | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs371035844; called by muse, mutect2, varscan2
- MYO9A | c.2878-1G>A p.X960_splice | Splice Site (SNP) | VAF 6/42 reads (14%) | catalogued as COSV100614114; called by muse, mutect2
- NBEAL2 | c.6074T>C p.I2025T | Missense Mutation (SNP) | VAF 42/238 reads (18%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV52760820; called by muse, mutect2
- NCAN | c.67G>A p.E23K | Missense Mutation (SNP) | VAF 31/141 reads (22%) | SIFT tolerated (0.19); PolyPhen benign (0.156); catalogued as COSV99388060; called by muse, mutect2, varscan2
- NEUROD4 | c.322G>A p.D108N | Missense Mutation (SNP) | VAF 17/96 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV54472614; called by muse, mutect2, varscan2
- NEXMIF | c.4455G>A p.L1485= | Splice Region (SNP) | VAF 6/24 reads (25%) | catalogued as COSV50021945, COSV50052798, COSV99281505; called by muse, mutect2, varscan2
- NFE2 | c.73G>A p.E25K | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.76); catalogued as COSV56456438; called by muse, mutect2, varscan2
- NGF | c.145C>T p.R49C | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.642); catalogued as rs146716262; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NLRC4 | c.1048G>A p.G350S | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV61593696; called by muse, mutect2, varscan2
- NLRP10 | c.1444G>A p.E482K | Missense Mutation (SNP) | VAF 34/134 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as COSV60781195; called by muse, mutect2, varscan2
- NLRP14 | c.1692G>A p.M564I | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT tolerated (0.97); PolyPhen benign (0); catalogued as COSV55069489; called by muse, mutect2, varscan2
- NMRK2 | c.146A>T p.D49V | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (0.14); PolyPhen probably damaging (1); catalogued as COSV99396483; called by muse, mutect2, varscan2
- NOS3 | c.901G>A p.E301K | Missense Mutation (SNP) | VAF 44/366 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.091); catalogued as COSV52495675; called by muse, mutect2
- NPIPB15 | c.1027C>T p.P343S | Missense Mutation (SNP) | VAF 14/148 reads (9%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.73); catalogued as COSV70437909; called by muse, mutect2
- NPSR1 | c.128C>T p.S43F | Missense Mutation (SNP) | VAF 17/115 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as rs267601496, COSV62204077; called by muse, mutect2, varscan2
- NQO1 | c.135G>A p.M45I | Missense Mutation (SNP) | VAF 20/110 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as COSV57732232; called by muse, mutect2, varscan2
- NRK | c.3092G>A p.S1031N | Missense Mutation (SNP) | VAF 13/24 reads (54%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0); catalogued as COSV54601289; called by muse, mutect2, varscan2
- NRXN2 | c.2672C>T p.P891L | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT tolerated (0.89); PolyPhen benign (0.009); catalogued as COSV55457867; called by muse, mutect2, varscan2
- NRXN3 | c.844G>A p.E282K | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.967); catalogued as COSV100202250; called by muse, mutect2
- NT5DC2 | c.1471C>T p.P491S | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT tolerated (0.26); PolyPhen benign (0.262); catalogued as COSV58739893; called by muse, mutect2, varscan2
- NUDT12 | c.1181C>T p.S394F | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV50091738; called by muse, mutect2, varscan2
- NYNRIN | c.4519T>C p.F1507L | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.18); PolyPhen benign (0.039); catalogued as COSV66843583; called by muse, mutect2, varscan2
- OGFOD1 | c.730C>T p.R244W | Missense Mutation (SNP) | VAF 43/144 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs745938796, COSV60201019; called by muse, mutect2, varscan2
- OPALIN | c.65A>T p.K22I | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT tolerated, low confidence (0.17); PolyPhen probably damaging (0.998); catalogued as COSV64520738; called by muse, mutect2, varscan2
- OR10A5 | c.563T>C p.L188P | Missense Mutation (SNP) | VAF 25/111 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55054942; called by muse, mutect2, varscan2
- OR1Q1 | c.680G>A p.R227Q | Missense Mutation (SNP) | VAF 30/100 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.02); catalogued as rs138056123; called by muse, mutect2, varscan2
- OR2G6 | c.23C>T p.S8F | Missense Mutation (SNP) | VAF 26/152 reads (17%) | SIFT tolerated (0.3); PolyPhen benign (0.23); catalogued as rs764665907, COSV58573865, COSV58575158; called by muse, mutect2, varscan2
- OR2G6 | c.482C>T p.S161F | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.697); catalogued as COSV58575175; called by muse, mutect2, varscan2
- OR4K2 | c.587G>A p.G196D | Missense Mutation (SNP) | VAF 40/229 reads (17%) | SIFT tolerated (0.24); PolyPhen benign (0.028); catalogued as rs747941898, COSV53850559; called by muse, mutect2, varscan2
- OR51L1 | c.268G>A p.D90N | Missense Mutation (SNP) | VAF 21/124 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV58625215, COSV58625562; called by muse, mutect2, varscan2
- OR51T1 | c.698G>A p.R233Q | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT tolerated (0.17); PolyPhen benign (0.063); catalogued as rs373780146; called by muse, mutect2, varscan2
- OR52R1 | c.485T>C p.F162S | Missense Mutation (SNP) | VAF 22/100 reads (22%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.472); catalogued as COSV61888874; called by muse, mutect2, varscan2
- OR5H6 | c.912G>A p.M304I (on ENST00000642105; = p.M288I on NM_001005479.2) | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as COSV101051740, COSV67351799; called by muse, mutect2, varscan2
- OR6M1 | c.445G>A p.G149R | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.81); catalogued as COSV58434121; called by muse, mutect2, varscan2
- PAIP2 | c.262C>T p.Q88* | Nonsense Mutation (SNP) | VAF 21/63 reads (33%) | catalogued as COSV54524824; called by muse, mutect2, varscan2
- PAK2 | c.926T>A p.F309Y | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV59083054; called by muse, mutect2, varscan2
- PAX4 | c.611C>G p.A204G | Missense Mutation (SNP) | VAF 32/110 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV58389861; called by muse, mutect2, varscan2
- PBRM1 | c.1082T>A p.L361* | Nonsense Mutation (SNP) | VAF 61/310 reads (20%) | catalogued as COSV56288110; called by muse, mutect2, varscan2
- PBX1 | c.1192G>A p.G398S | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT tolerated (0.51); PolyPhen benign (0.006); catalogued as rs146653553; called by muse, mutect2, varscan2
- PCDH15 | c.4642T>G p.F1548V | Missense Mutation (SNP) | VAF 22/86 reads (26%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.003); catalogued as COSV57348859; called by muse, mutect2, varscan2
- PCDHAC2 | c.1105G>A p.D369N | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.11); catalogued as COSV53859393, COSV99148275; called by muse, mutect2, varscan2
- PCDHB13 | c.1505C>T p.S502F | Missense Mutation (SNP) | VAF 67/306 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV53395261; called by muse, mutect2, varscan2
- PCDHB13 | c.1790G>A p.G597D | Missense Mutation (SNP) | VAF 22/139 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.982); catalogued as rs782519325, COSV99507673; called by muse, mutect2, varscan2
- PCDHB8 | c.538C>T p.R180W | Missense Mutation (SNP) | VAF 17/154 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.848); catalogued as rs267600428, COSV50753870; called by muse, mutect2, varscan2
- PCDHGA10 | c.1303C>A p.P435T | Missense Mutation (SNP) | VAF 33/182 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.612); catalogued as COSV53984824; called by muse, mutect2, varscan2
- PCDHGA9 | c.1693C>T p.P565S | Missense Mutation (SNP) | VAF 32/229 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV53944058; called by muse, mutect2, varscan2
- PCDHGB4 | c.2204C>T p.S735F | Missense Mutation (SNP) | VAF 61/306 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0.19); catalogued as COSV53984817; called by muse, mutect2, varscan2
- PCLO | c.11396G>A p.R3799Q | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs919590129, COSV61615295; called by muse, mutect2, varscan2
- PCLO | c.11246G>A p.R3749K | Missense Mutation (SNP) | VAF 14/94 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.039); catalogued as COSV61630870; called by muse, mutect2, varscan2
- PCLO | c.4798A>T p.K1600* | Nonsense Mutation (SNP) | VAF 33/193 reads (17%) | catalogued as COSV61648817; called by muse, mutect2, varscan2
- PCNT | c.4891G>A p.G1631S | Missense Mutation (SNP) | VAF 18/113 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.053); catalogued as rs1217043163, COSV100855919; called by muse, mutect2, varscan2
- PCNX2 | c.3290G>A p.W1097* | Nonsense Mutation (SNP) | VAF 6/64 reads (9%) | catalogued as COSV50803852; called by muse, mutect2
- PCSK1 | c.1622G>A p.R541Q | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT tolerated (0.2); PolyPhen benign (0.298); catalogued as rs1206346630, COSV60736405; called by muse, mutect2, varscan2
- PCYT1B | c.475G>A p.E159K | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.53); PolyPhen benign (0.036); catalogued as COSV63264889; called by muse, varscan2
- PDHA2 | c.636G>A p.W212* | Nonsense Mutation (SNP) | VAF 14/71 reads (20%) | catalogued as COSV54778995; called by muse, mutect2, varscan2
- PEX5L | c.268A>G p.K90E | Missense Mutation (SNP) | VAF 54/246 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.787); catalogued as COSV55850393; called by muse, mutect2, varscan2
- PFAS | c.98T>C p.L33P | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.584); catalogued as COSV58981793; called by muse, mutect2, varscan2
- PFKP | c.130C>T p.R44C | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs765385843, COSV66898508; called by muse, mutect2, varscan2
- PGBD1 | c.1198C>T p.P400S | Missense Mutation (SNP) | VAF 25/110 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.109); catalogued as rs373235441; called by muse, mutect2, varscan2
- PGBD5 | c.185C>T p.P62L (on ENST00000525115; = p.P131L on NM_001258311.2) | Missense Mutation (SNP) | VAF 41/99 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV58412597; called by muse, mutect2, varscan2
- PHKB | c.2332C>T p.L778F | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT tolerated (0.65); PolyPhen benign (0.302); catalogued as COSV54527028; called by muse, mutect2
- PLCB4 | c.2131C>T p.Q711* | Nonsense Mutation (SNP) | VAF 12/62 reads (19%) | catalogued as COSV53808651; called by muse, mutect2, varscan2
- PLCB4 | c.2263G>A p.E755K | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV53795583, COSV53808676; called by muse, mutect2, varscan2
- PLCZ1 | c.100C>T p.R34W | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.332); catalogued as rs376713289; called by muse, mutect2, varscan2
- PLEKHA7 | c.153G>A p.M51I | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0.043); catalogued as rs750783495, COSV63048393; called by muse, mutect2, varscan2
- PLEKHM2 | c.2177C>T p.A726V | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.37); catalogued as rs774436818, COSV65397113; called by muse, mutect2, varscan2
- PLK1 | c.968C>T p.P323L | Missense Mutation (SNP) | VAF 43/203 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55623118; called by muse, mutect2, varscan2
- PNPLA1 | c.1384+1G>A p.X462_splice (on ENST00000394571 / NM_001374623.1; = p.X367_splice on NM_173676.2) | Splice Site (SNP) | VAF 47/197 reads (24%) | catalogued as COSV57235866; called by muse, mutect2, varscan2
- POM121L12 | c.502G>A p.E168K | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT tolerated (0.27); PolyPhen benign (0.148); catalogued as COSV101374887, COSV68693476; called by muse, mutect2, varscan2
- PPP1R17 | c.235+1G>A p.X79_splice | Splice Site (SNP) | VAF 21/121 reads (17%) | catalogued as rs144626850; called by muse, mutect2, varscan2
- PRAG1 | c.434C>T p.P145L | Missense Mutation (SNP) | VAF 19/122 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0.287); catalogued as COSV58163968; called by muse, mutect2, varscan2
- PRAM1 | c.511G>A p.D171N | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated, low confidence (0.22); PolyPhen possibly damaging (0.741); catalogued as rs750049106, COSV55315199; called by muse, mutect2, varscan2
- PRKAR1A | c.1081C>T p.P361S | Missense Mutation (SNP) | VAF 14/129 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.803); catalogued as COSV56835746, COSV99873457; called by muse, mutect2
- PRKG2 | c.605G>A p.G202E | Missense Mutation (SNP) | VAF 29/108 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52327455; called by muse, mutect2, varscan2
- PRR14 | c.504G>A p.E168= | Splice Region (SNP) | VAF 9/29 reads (31%) | catalogued as COSV54912672; called by muse, mutect2, varscan2
- PSMD12 | c.299C>T p.A100V | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV62066235; called by muse, mutect2
- PSME4 | c.3098G>A p.G1033E | Missense Mutation (SNP) | VAF 25/105 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.22); catalogued as COSV66366293; called by muse, mutect2, varscan2
- PTPRM | c.2413G>A p.A805T | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.154); catalogued as COSV100159501; called by muse, mutect2, varscan2
- PTPRO | c.1228C>T p.R410* | Nonsense Mutation (SNP) | VAF 7/37 reads (19%) | catalogued as rs775473934, COSV55505505; called by muse, mutect2, varscan2
- PTPRT | c.484C>T p.Q162* | Nonsense Mutation (SNP) | VAF 39/191 reads (20%) | catalogued as rs267605939, COSV61982017, COSV61986603; called by muse, mutect2, varscan2
- PTPRZ1 | c.1676C>T p.S559F | Missense Mutation (SNP) | VAF 25/65 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.072); catalogued as COSV66441174; called by muse, mutect2, varscan2
- PXDNL | c.577G>A p.E193K | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT tolerated (0.26); PolyPhen benign (0.027); catalogued as rs758900873, COSV100681275, COSV62492958; called by muse, mutect2, varscan2
- PYDC1 | c.67T>C p.F23L | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57251768; called by muse, mutect2
- PYGL | c.521G>A p.G174E | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53587086; called by muse, mutect2, varscan2
- RABEP1 | c.2418A>C p.R806S | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT tolerated (0.42); PolyPhen benign (0.011); catalogued as COSV52586466; called by muse, mutect2, varscan2
- RABGAP1L | c.2267G>A p.R756K | Missense Mutation (SNP) | VAF 30/74 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV52309027; called by muse, mutect2, varscan2
- RABGEF1 | c.227G>A p.R76Q (on ENST00000439720 / NM_001287061.2; = p.R63Q on NM_014504.3 and 29 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT tolerated (0.2); PolyPhen benign (0.364); catalogued as rs1374327332, COSV99535053; called by muse, mutect2, varscan2
- RAD1 | c.211C>T p.Q71* | Nonsense Mutation (SNP) | VAF 8/35 reads (23%) | catalogued as COSV57715486; called by muse, mutect2, varscan2
- RAD18 | c.406T>A p.F136I | Missense Mutation (SNP) | VAF 18/120 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.209); catalogued as COSV53751544; called by muse, mutect2, varscan2
- RAD9B | c.305C>T p.S102F | Missense Mutation (SNP) | VAF 24/108 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.73); catalogued as COSV62195196; called by muse, mutect2, varscan2
- RAPGEF6 | c.3848C>T p.S1283F | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.823); catalogued as COSV57250344; called by muse, mutect2, varscan2
- RASSF6 | c.418C>T p.R140C (on ENST00000342081 / NM_201431.2; = p.R108C on NM_177532.5) | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.427); catalogued as rs142555062; called by muse, mutect2, varscan2
- RDH16 | c.5G>A p.W2* | Nonsense Mutation (SNP) | VAF 28/118 reads (24%) | catalogued as COSV62458443; called by muse, mutect2, varscan2
- RELB | c.439C>T p.R147C | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV55511610; called by muse, mutect2, varscan2
- RERGL | c.374G>A p.R125Q | Missense Mutation (SNP) | VAF 24/98 reads (24%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as rs369374785; called by muse, mutect2, varscan2
- RET | c.3095G>A p.G1032D | Missense Mutation (SNP) | VAF 50/200 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.548); catalogued as COSV60701082; called by muse, mutect2, varscan2
- RFX6 | c.2693C>T p.T898I | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.042); catalogued as COSV60587020; called by muse, mutect2, varscan2
- RHOD | c.245G>T p.R82L | Missense Mutation (SNP) | VAF 55/264 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58211402, COSV58211625; called by muse, mutect2, varscan2
- RNASE10 | c.205G>A p.V69M | Missense Mutation (SNP) | VAF 20/79 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.39); catalogued as rs201207144, COSV100116200; called by muse, mutect2, varscan2
- RNF213 | c.2136G>A p.W712* | Nonsense Mutation (SNP) | VAF 15/64 reads (23%) | catalogued as COSV60626123; called by muse, mutect2, varscan2
- ROR1 | c.2621C>T p.S874L | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.058); catalogued as COSV64289787; called by muse, mutect2, varscan2
- RPGRIP1 | c.1582C>G p.L528V | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.991); catalogued as COSV52852790; called by muse, mutect2, varscan2
- RPUSD1 | c.815C>T p.P272L | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.018); catalogued as COSV50101246; called by muse, mutect2
- RTN3 | c.1712T>G p.I571S (on ENST00000377819 / NM_001265589.2; = p.I552S on NM_201428.3) | Missense Mutation (SNP) | VAF 24/112 reads (21%) | SIFT tolerated (0.22); PolyPhen benign (0.026); catalogued as rs370047599, COSV58030159; called by muse, mutect2
- RTN3 | c.1714C>T p.L572F (on ENST00000377819 / NM_001265589.2; = p.L553F on NM_201428.3) | Missense Mutation (SNP) | VAF 24/109 reads (22%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.758); catalogued as COSV58028006, COSV58030167; called by muse, mutect2
- RUFY4 | c.760G>A p.E254K | Missense Mutation (SNP) | VAF 2/12 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0.14); catalogued as rs774470704, COSV60248438, COSV60248772; called by muse, mutect2
- RUNX1T1 | c.176C>T p.P59L (on ENST00000265814 / NM_001198628.1; = p.P32L on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT tolerated (0.38); PolyPhen benign (0.009); catalogued as rs552022984, COSV56154509; called by muse, varscan2
- RUNX1T1 | c.91C>T p.R31C (on ENST00000265814 / NM_001198628.1; = p.R4C on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as rs756333150, COSV56153978, COSV56159553; called by muse, varscan2
- RYR1 | c.1525G>A p.E509K | Missense Mutation (SNP) | VAF 19/98 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.842); catalogued as COSV62103174; called by muse, mutect2, varscan2
- SAMD9 | c.2524G>A p.E842K | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV66076588; called by muse, mutect2, varscan2
- SCAF1 | c.2788G>A p.G930R | Missense Mutation (SNP) | VAF 8/13 reads (62%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.246); catalogued as COSV62184037; called by muse, mutect2, varscan2
- SCN7A | c.2326G>A p.D776N | Missense Mutation (SNP) | VAF 28/99 reads (28%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV69273032; called by muse, mutect2, varscan2
- SEL1L3 | c.1126G>A p.D376N | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated (0.39); PolyPhen benign (0.005); catalogued as COSV53545075, COSV99341190; called by muse, mutect2, varscan2
- SERTAD3 | c.70G>A p.A24T | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT tolerated (0.79); PolyPhen benign (0.005); catalogued as COSV59325459; called by muse, mutect2, varscan2
- SF3A3 | c.674C>T p.T225I | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV65956216; called by muse, mutect2, varscan2
- SFI1 | c.1577G>A p.W526* (on ENST00000400288 / NM_001007467.3; = p.W495* on NM_014775.4) | Nonsense Mutation (SNP) | VAF 20/97 reads (21%) | catalogued as COSV66291773; called by muse, mutect2, varscan2
- SHANK2 | c.2932C>T p.R978C | Missense Mutation (SNP) | VAF 40/215 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs781820650, COSV53592985; called by muse, mutect2, varscan2
- SI | c.581T>C p.V194A | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.309); catalogued as COSV52288681; called by muse, mutect2, varscan2
- SIPA1L2 | c.1523C>T p.P508L | Missense Mutation (SNP) | VAF 82/240 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53394384; called by muse, mutect2, varscan2
- SIRPD | c.559C>G p.R187G | Missense Mutation (SNP) | VAF 22/104 reads (21%) | PolyPhen benign (0.005); catalogued as COSV67546950; called by muse, mutect2, varscan2
- SLC13A3 | c.679C>T p.R227C | Missense Mutation (SNP) | VAF 31/150 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.912); catalogued as rs866802774, COSV51717794; called by muse, mutect2, varscan2
- SLC14A2 | c.832G>A p.E278K | Missense Mutation (SNP) | VAF 23/82 reads (28%) | SIFT tolerated (0.27); PolyPhen benign (0.294); catalogued as COSV54911207; called by muse, mutect2, varscan2
- SLC16A1 | c.1202C>T p.P401L | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV63709807; called by muse, mutect2, varscan2
- SLC16A14 | c.643G>A p.G215S | Missense Mutation (SNP) | VAF 22/80 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1405653857, COSV54618626; called by muse, mutect2, varscan2
- SLC16A9 | c.298C>T p.P100S | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.999); catalogued as COSV68099664; called by muse, mutect2, varscan2
- SLC1A2 | c.1433G>A p.R478K | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53523614; called by muse, mutect2, varscan2
- SLC26A11 | c.175G>A p.G59S | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs1385633763, COSV58339833; called by muse, mutect2, varscan2
- SLC26A2 | c.1138C>T p.P380S | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (0.33); PolyPhen benign (0.241); catalogued as COSV53825031; called by muse, mutect2, varscan2
- SLC26A3 | c.1348G>A p.G450R | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60641287; called by muse, mutect2, varscan2
- SLC26A7 | c.256C>T p.P86S | Missense Mutation (SNP) | VAF 28/135 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52591505; called by muse, mutect2, varscan2
- SLC27A2 | c.630G>A p.W210* | Nonsense Mutation (SNP) | VAF 13/71 reads (18%) | catalogued as COSV51060608; called by muse, mutect2, varscan2
- SLC30A7 | c.539A>T p.N180I | Missense Mutation (SNP) | VAF 23/90 reads (26%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.942); catalogued as rs765826916, COSV63018095; called by muse, mutect2, varscan2
- SLC34A2 | c.1461C>T p.I487= | Splice Region (SNP) | VAF 12/40 reads (30%) | catalogued as rs867296079, COSV65942291; called by muse, mutect2, varscan2
- SLC35B3 | c.935C>T p.S312F | Missense Mutation (SNP) | VAF 17/106 reads (16%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.587); catalogued as COSV59469064; called by muse, mutect2, varscan2
- SLC4A1 | c.809G>A p.G270E | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV52260981; called by muse, mutect2, varscan2
- SLC4A10 | c.202C>G p.R68G | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.483); catalogued as COSV55771006, COSV99765297; called by muse, mutect2
- SLC4A1AP | c.2264C>T p.P755L | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as COSV58136129; called by muse, mutect2
- SLC9A1 | c.2108C>T p.S703L | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.017); catalogued as COSV56054986; called by muse, mutect2, varscan2
- SLFN11 | c.979G>A p.E327K | Missense Mutation (SNP) | VAF 23/93 reads (25%) | SIFT tolerated (0.65); PolyPhen benign (0.124); catalogued as rs1251178027, COSV57699645; called by muse, mutect2, varscan2
- SNAI2 | c.590C>T p.P197L | Missense Mutation (SNP) | VAF 22/113 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50079139, COSV99194996; called by muse, mutect2, varscan2
- SNX32 | c.235G>T p.E79* | Nonsense Mutation (SNP) | VAF 10/46 reads (22%) | catalogued as COSV57450052; called by muse, mutect2, varscan2
- SOCS5 | c.448C>T p.Q150* | Nonsense Mutation (SNP) | VAF 15/74 reads (20%) | catalogued as COSV60605641; called by muse, mutect2, varscan2
- SORL1 | c.2647C>T p.L883F | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV52757812, COSV99495637; called by muse, mutect2, varscan2
- SPEF2 | c.4177G>A p.E1393K | Missense Mutation (SNP) | VAF 28/126 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.719); catalogued as COSV57430613; called by muse, mutect2, varscan2
- SPTA1 | c.1066C>T p.R356C | Missense Mutation (SNP) | VAF 61/182 reads (34%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.901); catalogued as rs779418877, COSV63748977; called by muse, mutect2, varscan2
- SPTLC3 | c.853A>G p.R285G | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV65466892; called by muse, mutect2, varscan2
- SRGAP3 | c.1300G>A p.E434K | Missense Mutation (SNP) | VAF 17/92 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV64531169, COSV64542042; called by muse, mutect2, varscan2
- SRI | c.83C>T p.P28L | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.637); catalogued as COSV99719902; called by muse, mutect2, varscan2
- SRSF6 | c.595C>T p.R199* | Nonsense Mutation (SNP) | VAF 12/75 reads (16%) | catalogued as COSV54828226; called by muse, mutect2, varscan2
- ST6GAL2 | c.451C>T p.P151S | Missense Mutation (SNP) | VAF 38/262 reads (15%) | PolyPhen benign (0.015); catalogued as rs201546993, COSV64528458; called by muse, mutect2
- STK36 | c.2515C>T p.R839W | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.895); catalogued as rs867598239, COSV55324660; called by muse, mutect2, varscan2
- STON1-GTF2A1L | c.3017G>A p.R1006K | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT tolerated (0.86); PolyPhen benign (0.003); catalogued as rs201421811, COSV59133893; called by muse, mutect2, varscan2
- STRADB | c.113C>T p.S38F | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.049); catalogued as COSV52044069, COSV52044827; called by muse, mutect2, varscan2
- STRN3 | c.968C>T p.S323L | Missense Mutation (SNP) | VAF 31/131 reads (24%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.953); catalogued as rs199503536; called by muse, mutect2, varscan2
- STX6 | c.83G>A p.W28* | Nonsense Mutation (SNP) | VAF 30/110 reads (27%) | catalogued as rs745351491, COSV51113015; called by muse, mutect2, varscan2
- SV2C | c.1226G>C p.R409P | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.986); catalogued as COSV59221075, COSV59224262; called by muse, mutect2, varscan2
- SYNE2 | c.18540G>A p.E6180= | Splice Region (SNP) | VAF 4/36 reads (11%) | catalogued as COSV59958351; called by muse, mutect2, varscan2
- SYT10 | c.275A>C p.N92T | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as COSV57342622; called by muse, mutect2, varscan2
- SYT11 | c.805G>A p.D269N | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.996); catalogued as COSV64175369; called by muse, mutect2, varscan2
- SYTL2 | c.482C>T p.P161L | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs778208145, COSV60360942; called by muse, mutect2, varscan2
- TAP1 | c.1746G>A p.Q582= | Splice Region (SNP) | VAF 25/173 reads (14%) | catalogued as COSV62755081, COSV62755619; called by muse, mutect2, varscan2
- TAS2R5 | c.142A>T p.I48F | Missense Mutation (SNP) | VAF 33/90 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.029); catalogued as rs765326902, COSV56095238; called by muse, mutect2, varscan2
- TAS2R60 | c.586C>T p.P196S | Missense Mutation (SNP) | VAF 32/199 reads (16%) | SIFT tolerated (0.33); PolyPhen benign (0.191); catalogued as COSV60331418; called by muse, mutect2, varscan2
- TBC1D31 | c.344C>T p.T115I | Missense Mutation (SNP) | VAF 33/157 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV99783090; called by muse, mutect2, varscan2
- TDRD7 | c.3121C>G p.R1041G | Missense Mutation (SNP) | VAF 27/141 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62429379, COSV62430190; called by muse, mutect2, varscan2
- TENM1 | c.5053G>A p.E1685K | Missense Mutation (SNP) | VAF 36/105 reads (34%) | SIFT tolerated (0.46); PolyPhen benign (0.11); catalogued as COSV64437175; called by muse, mutect2, varscan2
- TENM3 | c.6643C>T p.R2215* | Nonsense Mutation (SNP) | VAF 15/88 reads (17%) | catalogued as COSV69313512; called by muse, mutect2, varscan2
- TEX11 | c.1420G>A p.D474N (on ENST00000344304; = p.D459N on NM_031276.3) | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.852); catalogued as COSV60234299; called by muse, mutect2, varscan2
- TFIP11 | c.335A>G p.K112R | Missense Mutation (SNP) | VAF 27/103 reads (26%) | SIFT tolerated (0.6); PolyPhen benign (0.01); catalogued as COSV68021041; called by muse, mutect2, varscan2
- TGFBRAP1 | c.1204C>T p.P402S | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.205); catalogued as COSV99305387; called by muse, mutect2, varscan2
- THBS4 | c.2855A>G p.Q952R | Missense Mutation (SNP) | VAF 34/145 reads (23%) | SIFT tolerated (0.98); PolyPhen benign (0.228); catalogued as COSV63470113; called by muse, mutect2, varscan2
- THOC2 | c.3746C>T p.P1249L | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as COSV99833982; called by muse, mutect2, varscan2
- THOC2 | c.3745C>T p.P1249S | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT tolerated (0.6); PolyPhen benign (0.039); catalogued as COSV99833983; called by muse, mutect2, varscan2
- THPO | c.1201T>A p.F401I (on ENST00000649095 / NM_001290003.1; = p.F261I on NM_000460.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 45/186 reads (24%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.794); catalogued as COSV99201216; called by muse, mutect2, varscan2
- TICRR | c.3471A>T p.L1157F | Missense Mutation (SNP) | VAF 29/165 reads (18%) | SIFT tolerated (0.28); PolyPhen benign (0.007); catalogued as COSV51540335, COSV51543891; called by muse, mutect2, varscan2
- TIGD4 | c.473C>T p.P158L | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.01); catalogued as rs1237404771, COSV100428041; called by muse, mutect2, varscan2
- TIGD4 | c.472C>T p.P158S | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT tolerated (0.53); PolyPhen benign (0.015); catalogued as COSV100428044; called by muse, mutect2, varscan2
- TLL1 | c.1330C>T p.R444C | Missense Mutation (SNP) | VAF 27/115 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1452918005, COSV50269380; called by muse, mutect2, varscan2
- TMEM108 | c.239C>T p.P80L | Missense Mutation (SNP) | VAF 31/126 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.023); catalogued as rs1235322087, COSV58876236; called by muse, mutect2, varscan2
- TMEM132D | c.1271A>C p.D424A | Missense Mutation (SNP) | VAF 30/200 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.225); catalogued as COSV70613646; called by muse, mutect2, varscan2
- TMEM174 | c.508G>A p.G170R | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.651); catalogued as COSV57113688; called by muse, mutect2, varscan2
- TMPRSS9 | c.1454C>A p.A485D (on ENST00000648592; = p.A451D on NM_182973.2) | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.206); catalogued as COSV100211638; called by muse, mutect2
- TNC | c.718G>A p.E240K | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.545); catalogued as rs748129315, COSV60787227; called by muse, mutect2, varscan2
- TNIK | c.2281C>T p.R761* | Nonsense Mutation (SNP) | VAF 4/15 reads (27%) | catalogued as COSV52679451; called by muse, mutect2
- TNKS | c.3121G>A p.E1041K | Missense Mutation (SNP) | VAF 15/94 reads (16%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.677); catalogued as COSV60062294; called by muse, mutect2, varscan2
- TNS2 | c.1453C>T p.Q485* (on ENST00000314250 / NM_170754.4; = p.Q495* on NM_015319.2) | Nonsense Mutation (SNP) | VAF 29/124 reads (23%) | catalogued as COSV58579617; called by muse, mutect2, varscan2
- TNXB | c.5500G>A p.D1834N (on ENST00000647633; = p.D1587N on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.917); catalogued as COSV64483178; called by muse, mutect2, varscan2
- TP53BP1 | c.2261C>T p.S754F | Missense Mutation (SNP) | VAF 24/106 reads (23%) | SIFT tolerated, low confidence (0.31); PolyPhen probably damaging (0.991); catalogued as rs1270167248, COSV55504609; called by muse, mutect2, varscan2
- TP53BP1 | c.1648C>T p.P550S | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.996); catalogued as rs1342330619, COSV55504621; called by muse, mutect2, varscan2
- TRIM42 | c.1541C>G p.T514R | Missense Mutation (SNP) | VAF 26/104 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.031); catalogued as COSV53884800; called by muse, mutect2, varscan2
- TRIML2 | c.416C>T p.T139I | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.023); catalogued as rs745486224, COSV58717851; called by muse, mutect2, varscan2
- TRPV5 | c.2143G>A p.G715R | Missense Mutation (SNP) | VAF 35/115 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.426); catalogued as COSV54682840, COSV54687757; called by muse, mutect2, varscan2
- TSPYL2 | c.484C>T p.P162S | Missense Mutation (SNP) | VAF 2/14 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.702); catalogued as rs147809315; called by muse, mutect2
- TSSK1B | c.793G>A p.E265K | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.206); catalogued as rs762006295, COSV66815637; called by muse, mutect2, varscan2
- TTN | c.84420G>A p.W28140* (on ENST00000591111; = p.W20716* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 8/67 reads (12%) | catalogued as COSV60184429; called by muse, mutect2, varscan2
- TTN | c.79471G>A p.E26491K (on ENST00000591111; = p.E19067K on NM_003319.4) | Missense Mutation (SNP) | VAF 5/39 reads (13%) | PolyPhen probably damaging (0.994); catalogued as COSV60184461; called by muse, mutect2, varscan2
- TTN | c.73766G>T p.G24589V (on ENST00000591111; = p.G17165V on NM_003319.4) | Missense Mutation (SNP) | VAF 17/77 reads (22%) | PolyPhen probably damaging (0.993); catalogued as COSV60282485; called by muse, mutect2, varscan2
- TTN | c.73765G>T p.G24589* (on ENST00000591111; = p.G17165* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 17/77 reads (22%) | catalogued as COSV100625122; called by muse, mutect2, varscan2
- TTN | c.47966C>T p.T15989I (on ENST00000591111; = p.T8565I on NM_003319.4) | Missense Mutation (SNP) | VAF 26/134 reads (19%) | PolyPhen benign (0.09); catalogued as COSV59999372, COSV60184490; called by muse, varscan2
- TTN | c.39371G>A p.G13124D (on ENST00000591111; = p.G5700D on NM_003319.4) | Missense Mutation (SNP) | VAF 13/88 reads (15%) | PolyPhen probably damaging (0.964); catalogued as rs772788193, COSV60184527; called by muse, mutect2, varscan2
- TXNDC11 | c.304T>C p.S102P | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated (0.27); PolyPhen benign (0.076); catalogued as COSV51601089; called by muse, mutect2, varscan2
- UBIAD1 | c.370C>T p.R124* | Nonsense Mutation (SNP) | VAF 18/61 reads (30%) | catalogued as COSV100954929; called by muse, mutect2, varscan2
- UBN1 | c.109G>T p.D37Y | Missense Mutation (SNP) | VAF 13/89 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV52170085; called by muse, mutect2, varscan2
- UBR2 | c.4613C>T p.P1538L | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV65751091; called by muse, mutect2, varscan2
- UGT2B11 | c.14G>A p.W5* | Nonsense Mutation (SNP) | VAF 39/197 reads (20%) | catalogued as rs772574972, COSV71423640; called by muse, mutect2, varscan2
- UNC13C | c.5160C>T p.F1720= | Splice Region (SNP) | VAF 10/47 reads (21%) | catalogued as COSV52897272; called by muse, mutect2, varscan2
- UNC45B | c.1738G>A p.V580M | Missense Mutation (SNP) | VAF 22/109 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV52098084; called by muse, mutect2, varscan2
- UNK | c.1548G>A p.E516= | Splice Region (SNP) | VAF 20/78 reads (26%) | catalogued as rs1013788738, COSV53144329; called by muse, mutect2, varscan2
- UTP6 | c.967G>A p.E323K | Missense Mutation (SNP) | VAF 31/147 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.11); catalogued as rs542178063, COSV55574337; called by muse, mutect2, varscan2
- VAC14 | c.1772C>T p.T591I | Missense Mutation (SNP) | VAF 19/113 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.077); catalogued as COSV55755448; called by muse, mutect2, varscan2
- VAV1 | c.1511C>T p.S504F | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV58387261; called by muse, mutect2
- VDR | c.847G>C p.D283H | Missense Mutation (SNP) | VAF 16/86 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.842); catalogued as COSV57469067; called by muse, mutect2, varscan2
- VEGFC | c.1157G>A p.R386Q | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT tolerated (0.32); PolyPhen benign (0.198); catalogued as rs368084817; called by muse, mutect2, varscan2
- VEGFC | c.559G>A p.E187K | Missense Mutation (SNP) | VAF 32/129 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV54595855; called by muse, mutect2, varscan2
- VRTN | c.1259C>T p.P420L | Missense Mutation (SNP) | VAF 20/107 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1398336250, COSV56442259; called by muse, mutect2, varscan2
- VSTM2L | c.506C>T p.S169F | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.537); catalogued as COSV65096270; called by muse, mutect2
- VWA3A | c.1220C>T p.S407F | Missense Mutation (SNP) | VAF 21/100 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as rs1252272779, COSV55393148; called by muse, mutect2, varscan2
- WIZ | c.5581A>G p.I1861V (on ENST00000673675 / NM_001371589.1; = p.I766V on NM_021241.3) | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs760336135, COSV54609726; called by muse, mutect2, varscan2
- WNT2 | c.1021G>A p.E341K | Missense Mutation (SNP) | VAF 19/119 reads (16%) | SIFT tolerated (0.33); PolyPhen benign (0.05); catalogued as COSV55412293; called by muse, mutect2, varscan2
- XIRP2 | c.6992G>A p.G2331E (on ENST00000628543; = p.G2506E on NM_152381.6) | Missense Mutation (SNP) | VAF 15/95 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54715957; called by muse, mutect2, varscan2
- XRCC6 | c.457C>T p.L153F | Missense Mutation (SNP) | VAF 15/88 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.109); catalogued as COSV63753296; called by muse, mutect2, varscan2
- ZAN | c.5579C>T p.S1860F | Missense Mutation (SNP) | VAF 28/72 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.834); catalogued as COSV61811763; called by muse, mutect2, varscan2
- ZAN | c.5843C>T p.S1948F | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as COSV61811771; called by muse, mutect2, varscan2
- ZDBF2 | c.5050C>T p.H1684Y | Missense Mutation (SNP) | VAF 9/76 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as COSV65627886; called by muse, mutect2, varscan2
- ZFP2 | c.613G>A p.E205K | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.096); catalogued as COSV63726350; called by muse, mutect2, varscan2
- ZFP42 | c.757G>A p.G253R | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.937); catalogued as COSV58818297; called by muse, mutect2, varscan2
- ZFP69 | c.97G>A p.E33K | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0.055); catalogued as rs767024803, COSV65529272; called by muse, mutect2, varscan2
- ZNF236 | c.4615C>T p.P1539S | Missense Mutation (SNP) | VAF 30/94 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.021); catalogued as COSV53492355; called by muse, mutect2, varscan2
- ZNF365 | c.1031G>A p.R344K | Missense Mutation (SNP) | VAF 26/123 reads (21%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.352); catalogued as rs760302065, COSV101237979; called by muse, mutect2, varscan2
- ZNF385D | c.76C>T p.P26S | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.068); catalogued as COSV55764669; called by muse, mutect2, varscan2
- ZNF496 | c.1295A>G p.E432G | Missense Mutation (SNP) | VAF 15/129 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.544); catalogued as COSV54179691; called by muse, mutect2, varscan2
- ZNF516 | c.2366C>T p.S789F | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.879); catalogued as COSV71587326; called by muse, mutect2, varscan2
- ZNF568 | c.1417C>G p.P473A | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV61742161; called by muse, mutect2, varscan2
- ZNF571 | c.209G>A p.W70* | Nonsense Mutation (SNP) | VAF 15/65 reads (23%) | catalogued as rs1000732555, COSV100143933; called by muse, mutect2, varscan2
- ZNF584 | c.722C>T p.P241L | Missense Mutation (SNP) | VAF 19/37 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV59722898; called by muse, mutect2, varscan2
- ZNF646 | c.118G>A p.E40K | Missense Mutation (SNP) | VAF 22/131 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as rs1191105821, COSV56216545; called by muse, mutect2, varscan2
- ZNF665 | c.493G>A p.G165R (on ENST00000600412; = p.G230R on NM_024733.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 34/91 reads (37%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.999); catalogued as rs1181748954, COSV67216307; called by muse, varscan2
- ZNF691 | c.803C>T p.S268F (on ENST00000372502; = p.S237F on NM_015911.3) | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV65289464; called by muse, mutect2, varscan2
- ZNF692 | c.1382_1385del p.D461Vfs*15 | Frame Shift Del (DEL) | VAF 22/143 reads (15%) | catalogued as rs779145082; called by mutect2, pindel, varscan2
- ZNF711 | c.1837C>T p.H613Y | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52156612; called by muse, mutect2, varscan2
- ZNF79 | c.28C>T p.P10S | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV61071356; called by muse, mutect2, varscan2
- ZNF81 | c.1574C>T p.S525F | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV58577275; called by muse, mutect2, varscan2
- ZSCAN21 | c.361G>C p.E121Q | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1303461267, COSV52851445; called by muse, mutect2, varscan2
- ZSCAN29 | c.1532C>T p.S511F | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT tolerated (0.21); PolyPhen benign (0.166); catalogued as COSV67822962; called by muse, mutect2, varscan2
- GABRB2 | c.1084del p.Y362Ifs*45 | Frame Shift Del (DEL) | VAF 6/28 reads (21%) | called by mutect2, pindel
- IKZF1 | c.410G>A p.R137K | Missense Mutation (SNP) | VAF 29/68 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- KIR2DL1 | c.223G>A p.E75K | Missense Mutation (SNP) | VAF 102/490 reads (21%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.761); called by muse, varscan2
- MEMO1 | c.509del p.G170Efs*8 | Frame Shift Del (DEL) | VAF 23/103 reads (22%) | called by mutect2, pindel, varscan2
- MRE11 | c.784del p.Y262Ifs*19 | Frame Shift Del (DEL) | VAF 7/60 reads (12%) | called by mutect2, varscan2
- OR4Q3 | c.503A>C p.Q168P | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PBRM1 | c.3639dup p.E1214Rfs*6 (on ENST00000296302 / NM_001366071.2; = p.E1189Rfs*6 on NM_018313.5) | Frame Shift Ins (INS) | VAF 10/58 reads (17%) | called by mutect2, pindel, varscan2
- SLC30A5 | c.1392dup p.A465Cfs*6 | Frame Shift Ins (INS) | VAF 16/103 reads (16%) | called by mutect2, pindel, varscan2
- TRAV19 | c.281C>T p.S94F | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.22); called by muse, mutect2
- TRAV9-1 | c.226G>A p.G76R | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- ABCA2 | c.5862C>T p.F1954= (on ENST00000614293; = p.F1924= on NM_001606.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 5/12 reads (42%) | catalogued as COSV55803703; called by muse, mutect2, varscan2
- ACAD10 | c.2604C>T p.I868= | Silent (SNP) | VAF 24/123 reads (20%) | catalogued as COSV58159488; called by muse, mutect2, varscan2
- ACO2 | c.90C>A p.A30= | Silent (SNP) | VAF 68/313 reads (22%) | catalogued as rs778272400, COSV53444016; called by muse, mutect2, varscan2
- ADAM28 | c.231C>T p.N77= | Silent (SNP) | VAF 5/34 reads (15%) | catalogued as rs1179288914, COSV56102471; called by muse, mutect2
- ADAM7 | c.309C>T p.I103= | Silent (SNP) | VAF 15/60 reads (25%) | catalogued as COSV51540019, COSV51543007; called by muse, mutect2, varscan2
- ADAMTSL4 | c.2619G>A p.G873= | Silent (SNP) | VAF 8/42 reads (19%) | catalogued as COSV55003201; called by muse, mutect2, varscan2
- ADGRV1 | c.11466C>T p.F3822= | Silent (SNP) | VAF 12/83 reads (14%) | catalogued as COSV67989874; called by muse, mutect2, varscan2
- ALX1 | c.117C>T p.S39= | Silent (SNP) | VAF 26/103 reads (25%) | catalogued as COSV57493075; called by muse, mutect2, varscan2
- AMDHD1 | c.1280G>A p.*427= | Silent (SNP) | VAF 4/9 reads (44%) | catalogued as COSV54118906; called by muse, mutect2, varscan2
- AMPD2 | c.504C>T p.V168= | Silent (SNP) | VAF 6/30 reads (20%) | catalogued as COSV56649096; called by muse, mutect2, varscan2
- ANKRD30A | c.3180G>A p.R1060= (on ENST00000611781; = p.R1004= on NM_052997.2) | Silent (SNP) | VAF 4/34 reads (12%) | catalogued as COSV64615180; called by muse, mutect2
- ANO2 | c.423G>A p.L141= (on ENST00000356134 / NM_001278597.3; = p.L145= on NM_001278596.3) | Silent (SNP) | VAF 14/58 reads (24%) | catalogued as COSV59032659; called by muse, mutect2, varscan2
- AOC3 | c.1797C>T p.H599= | Silent (SNP) | VAF 11/55 reads (20%) | catalogued as COSV53827791; called by muse, mutect2, varscan2
- AP2B1 | c.663C>T p.F221= | Silent (SNP) | VAF 19/79 reads (24%) | catalogued as COSV52001107; called by muse, mutect2, varscan2
- APOF | c.877C>T p.L293= | Silent (SNP) | VAF 11/70 reads (16%) | catalogued as COSV58476343; called by muse, mutect2, varscan2
- ARHGAP4 | c.27G>A p.R9= | Silent (SNP) | VAF 14/21 reads (67%) | catalogued as COSV63133157; called by muse, mutect2, varscan2
- ARMC12 | c.519C>T p.L173= (on ENST00000373866 / NM_001286574.2; = p.L200= on NM_145028.5) | Silent (SNP) | VAF 19/112 reads (17%) | catalogued as COSV55360667; called by muse, mutect2, varscan2
- ARMC9 | c.1545C>T p.N515= | Silent (SNP) | VAF 20/100 reads (20%) | catalogued as COSV63022292; called by muse, mutect2, varscan2
- ASAP3 | c.378C>T p.F126= | Silent (SNP) | VAF 51/179 reads (28%) | catalogued as rs1381040081, COSV60876160; called by muse, mutect2, varscan2
- ASPDH | c.792C>T p.F264= (on ENST00000389208 / NM_001114598.2; = p.F159= on NM_001024656.3) | Silent (SNP) | VAF 4/9 reads (44%) | catalogued as COSV65350340, COSV65350843; called by muse, varscan2
- ASTN2 | c.726G>A p.K242= | Silent (SNP) | VAF 16/52 reads (31%) | catalogued as COSV57795748, COSV57816477; called by muse, varscan2
- ATG9A | c.222C>T p.L74= | Silent (SNP) | VAF 8/49 reads (16%) | catalogued as COSV60134031; called by muse, mutect2, varscan2
- ATP13A4 | c.870G>A p.G290= | Silent (SNP) | VAF 44/184 reads (24%) | catalogued as rs1425406815, COSV99795097; called by muse, mutect2, varscan2
- BCAS3 | c.2494C>T p.L832= (on ENST00000390652 / NM_001353144.2; = p.L817= on NM_017679.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 27/158 reads (17%) | catalogued as COSV66777352; called by muse, mutect2, varscan2
- BIRC3 | c.771C>T p.A257= | Silent (SNP) | VAF 8/66 reads (12%) | catalogued as COSV54818401, COSV54818658; called by muse, mutect2, varscan2
- BRINP1 | c.738C>T p.A246= | Silent (SNP) | VAF 11/53 reads (21%) | catalogued as COSV56306021; called by muse, mutect2, varscan2
- C11orf42 | c.366G>A p.K122= | Silent (SNP) | VAF 27/121 reads (22%) | catalogued as COSV56412883; called by muse, mutect2, varscan2
- C2orf16 | c.4842C>T p.H1614= | Silent (SNP) | VAF 22/120 reads (18%) | catalogued as rs1467740492, COSV62676888; called by muse, mutect2, varscan2
- CAPNS2 | c.321C>T p.V107= | Silent (SNP) | VAF 24/128 reads (19%) | catalogued as COSV50897055; called by muse, mutect2, varscan2
- CDCA2 | c.991C>T p.L331= | Silent (SNP) | VAF 6/42 reads (14%) | catalogued as COSV57947106; called by muse, mutect2, varscan2
- CEMIP | c.3636G>A p.E1212= | Silent (SNP) | VAF 29/113 reads (26%) | catalogued as rs770916201, COSV54996196; called by muse, mutect2, varscan2
- CFAP100 | c.1233G>A p.T411= | Silent (SNP) | VAF 16/88 reads (18%) | catalogued as rs1291825940, COSV61503713; called by muse, mutect2, varscan2
- CHD5 | c.534G>A p.K178= | Silent (SNP) | VAF 13/73 reads (18%) | catalogued as COSV52419732; called by muse, mutect2, varscan2
- CHI3L1 | c.906C>T p.F302= | Silent (SNP) | VAF 33/68 reads (49%) | catalogued as rs372170408, COSV55138233; called by muse, mutect2, varscan2
- CHRNB4 | c.183C>T p.S61= | Silent (SNP) | VAF 22/128 reads (17%) | catalogued as COSV55716970; called by muse, mutect2, varscan2
- CHRND | c.330C>T p.L110= | Silent (SNP) | VAF 13/92 reads (14%) | catalogued as COSV99286072; called by muse, mutect2, varscan2
- CLYBL | c.180G>A p.K60= | Silent (SNP) | VAF 25/90 reads (28%) | catalogued as COSV59224697; called by muse, mutect2, varscan2
- CMTR1 | c.1974C>T p.I658= | Silent (SNP) | VAF 5/22 reads (23%) | catalogued as rs1208214369, COSV65090911; called by muse, mutect2, varscan2
- CNTNAP1 | c.531C>T p.F177= | Silent (SNP) | VAF 17/86 reads (20%) | catalogued as rs763570245, COSV52850612; called by muse, mutect2, varscan2
- COL5A1 | c.2400C>T p.I800= | Silent (SNP) | VAF 30/113 reads (27%) | catalogued as rs539234463, COSV65671734; called by muse, mutect2, varscan2
- COPS7B | c.225C>T p.Y75= | Silent (SNP) | VAF 11/61 reads (18%) | catalogued as COSV100602298; called by muse, mutect2, varscan2
- CPNE1 | c.375G>C p.G125= (on ENST00000352393; = p.G130= on NM_003915.5) | Silent (SNP) | VAF 11/36 reads (31%) | catalogued as COSV58293142; called by muse, mutect2, varscan2
- CPNE7 | c.1740C>T p.F580= | Silent (SNP) | VAF 17/76 reads (22%) | catalogued as rs544901695, COSV52014313; called by muse, mutect2, varscan2
- CRYBB2 | c.279C>T p.S93= | Silent (SNP) | VAF 22/110 reads (20%) | catalogued as rs371287851; ClinVar: likely benign; called by muse, mutect2, varscan2
- CTSA | c.258C>T p.P86= | Silent (SNP) | VAF 20/77 reads (26%) | catalogued as rs766977905, COSV51943390; called by muse, mutect2, varscan2
- CXCR1 | c.636C>T p.I212= | Silent (SNP) | VAF 20/95 reads (21%) | catalogued as rs755849655, COSV55281689; called by muse, mutect2, varscan2
- CYP4F8 | c.318C>T p.I106= | Silent (SNP) | VAF 32/176 reads (18%) | catalogued as rs375063511, COSV100358293; called by muse, mutect2, varscan2
- CYP4Z1 | c.243C>T p.P81= | Silent (SNP) | VAF 30/152 reads (20%) | catalogued as rs776845255, COSV61965701; called by muse, mutect2, varscan2
- DCST1 | c.666G>A p.R222= | Silent (SNP) | VAF 44/110 reads (40%) | catalogued as COSV55061011; called by muse, mutect2, varscan2
- DGLUCY | c.1200C>T p.I400= | Silent (SNP) | VAF 6/39 reads (15%) | catalogued as COSV56367909; called by muse, mutect2, varscan2
- DHFR2 | c.171C>T p.T57= | Silent (SNP) | VAF 44/209 reads (21%) | catalogued as COSV58936528; called by muse, mutect2, varscan2
- DHRS13 | c.822C>T p.I274= | Silent (SNP) | VAF 6/33 reads (18%) | catalogued as rs146651013; called by muse, mutect2, varscan2
- DLL1 | c.1836C>T p.I612= | Silent (SNP) | VAF 38/151 reads (25%) | catalogued as COSV64538003; called by muse, mutect2, varscan2
- DNAH5 | c.8893C>T p.L2965= | Silent (SNP) | VAF 6/35 reads (17%) | catalogued as COSV54238456; called by muse, mutect2
- DPPA5 | c.165C>T p.L55= | Silent (SNP) | VAF 18/69 reads (26%) | catalogued as rs769245148, COSV64875704, COSV64875797; called by muse, mutect2, varscan2
- DRD2 | c.675C>T p.T225= | Silent (SNP) | VAF 26/162 reads (16%) | catalogued as COSV60760143; called by muse, mutect2, varscan2
- DYTN | c.723C>T p.Y241= | Silent (SNP) | VAF 11/60 reads (18%) | catalogued as COSV71752534; called by muse, mutect2
- EIF3D | c.1341C>T p.L447= | Silent (SNP) | VAF 29/139 reads (21%) | catalogued as COSV53404311; called by muse, mutect2, varscan2
- EML3 | c.591C>T p.S197= | Silent (SNP) | VAF 56/220 reads (25%) | catalogued as rs563705722, COSV53883361; called by muse, mutect2, varscan2
- ENPP6 | c.39C>T p.A13= | Silent (SNP) | VAF 12/37 reads (32%) | catalogued as COSV57069838; called by muse, mutect2, varscan2
- EPB41L1 | c.2643C>T p.S881= | Silent (SNP) | VAF 6/43 reads (14%) | catalogued as rs758200297, COSV52440597; called by muse, mutect2, varscan2
- EPB41L5 | c.567C>T p.F189= | Silent (SNP) | VAF 36/144 reads (25%) | catalogued as rs772402705, COSV55354598; called by muse, mutect2, varscan2
- EPHA10 | c.2778C>T p.D926= | Silent (SNP) | VAF 4/36 reads (11%) | catalogued as COSV57625308; called by muse, mutect2
- ERN2 | c.1224G>A p.E408= | Silent (SNP) | VAF 29/102 reads (28%) | catalogued as COSV56835539; called by muse, mutect2, varscan2
- EXOC3L4 | c.258C>T p.S86= | Silent (SNP) | VAF 7/39 reads (18%) | catalogued as COSV66295748; called by muse, mutect2
- EYA1 | c.1300T>C p.L434= | Silent (SNP) | VAF 20/103 reads (19%) | catalogued as COSV58167851; called by muse, mutect2, varscan2
- FASTKD1 | c.393C>T p.A131= | Silent (SNP) | VAF 30/155 reads (19%) | catalogued as COSV70007058; called by muse, mutect2, varscan2
- FCRL3 | c.1275G>A p.G425= | Silent (SNP) | VAF 62/197 reads (31%) | catalogued as COSV63843232; called by muse, mutect2, varscan2
- FGF19 | c.495C>T p.F165= | Silent (SNP) | VAF 32/182 reads (18%) | catalogued as COSV53735856; called by muse, mutect2, varscan2
- FGL2 | c.159G>A p.G53= | Silent (SNP) | VAF 28/170 reads (16%) | catalogued as COSV50383414; called by muse, mutect2, varscan2
- FLG | c.117G>A p.K39= | Silent (SNP) | VAF 32/193 reads (17%) | catalogued as COSV64241707, COSV64244634, COSV64245696; called by muse, mutect2, varscan2
- FLRT1 | c.1821G>A p.K607= | Silent (SNP) | VAF 13/72 reads (18%) | catalogued as rs149018598; called by muse, mutect2, varscan2
- FUT6 | c.930G>A p.K310= | Silent (SNP) | VAF 6/61 reads (10%) | catalogued as COSV99744865; called by muse, mutect2, varscan2
- FYCO1 | c.2349G>A p.G783= | Silent (SNP) | VAF 19/72 reads (26%) | catalogued as COSV56117598; called by muse, mutect2, varscan2
- GABRA6 | c.1041G>A p.V347= | Silent (SNP) | VAF 12/78 reads (15%) | catalogued as COSV50885603; called by muse, mutect2, varscan2
- GABRD | c.288G>A p.R96= | Silent (SNP) | VAF 29/125 reads (23%) | catalogued as COSV66081291; called by muse, mutect2, varscan2
- GALNT15 | c.360C>T p.I120= | Silent (SNP) | VAF 7/40 reads (18%) | catalogued as COSV60218343; called by muse, mutect2, varscan2
- GAREM1 | c.957C>T p.P319= | Silent (SNP) | VAF 18/56 reads (32%) | catalogued as rs765838313, COSV99330731; called by muse, mutect2, varscan2
- GFOD1 | c.996C>T p.T332= | Silent (SNP) | VAF 18/97 reads (19%) | catalogued as COSV64954978; called by muse, mutect2, varscan2
- GJA4 | c.54G>A p.S18= | Silent (SNP) | VAF 12/52 reads (23%) | catalogued as rs143380983; called by muse, mutect2, varscan2
- GJA8 | c.18C>T p.F6= | Silent (SNP) | VAF 36/225 reads (16%) | catalogued as COSV53789519; called by muse, mutect2, varscan2
- GPD2 | c.1147C>T p.L383= | Silent (SNP) | VAF 4/37 reads (11%) | catalogued as COSV60094634; called by muse, mutect2
- GPR179 | c.1710G>A p.S570= (on ENST00000621958; = p.S569= on NM_001004334.4) | Silent (SNP) | VAF 4/28 reads (14%) | catalogued as rs376899590; called by muse, mutect2, varscan2
- GPR26 | c.102G>A p.A34= | Silent (SNP) | VAF 6/13 reads (46%) | catalogued as COSV99501043; called by muse, mutect2, varscan2
- GPRC5B | c.297C>T p.F99= | Silent (SNP) | VAF 9/54 reads (17%) | catalogued as COSV56027525; called by muse, mutect2, varscan2
- GPRIN2 | c.819G>A p.Q273= | Silent (SNP) | VAF 9/73 reads (12%) | catalogued as COSV65401653; called by muse, mutect2, varscan2
- GRM5 | c.408C>T p.S136= | Silent (SNP) | VAF 18/74 reads (24%) | catalogued as COSV59614913; called by muse, mutect2, varscan2
- GUCY2C | c.2052C>T p.S684= | Silent (SNP) | VAF 13/59 reads (22%) | catalogued as COSV53792524; called by muse, mutect2, varscan2
- H1-7 | c.303G>A p.R101= | Silent (SNP) | VAF 9/49 reads (18%) | catalogued as COSV58602550; called by muse, mutect2, varscan2
- HERC2 | c.780C>T p.F260= | Silent (SNP) | VAF 6/50 reads (12%) | catalogued as COSV55335423; called by muse, mutect2
- HK2 | c.519G>A p.K173= | Silent (SNP) | VAF 36/158 reads (23%) | catalogued as COSV99309453; called by muse, mutect2, varscan2
- HTT | c.7608G>A p.L2536= | Silent (SNP) | VAF 12/61 reads (20%) | catalogued as rs775119502, COSV61865326; called by muse, mutect2, varscan2
- ICE1 | c.1278C>T p.I426= | Silent (SNP) | VAF 3/20 reads (15%) | called by muse, mutect2
- IGHM | c.180G>A p.L60= | Silent (SNP) | VAF 9/45 reads (20%) | called by muse, mutect2, varscan2
- IGHV1-2 | c.21C>T p.I7= | Silent (SNP) | VAF 6/40 reads (15%) | catalogued as rs571786371; called by muse, mutect2, varscan2
- IGHV2-5 | c.63C>T p.I21= | Silent (SNP) | VAF 8/38 reads (21%) | catalogued as rs575643371; called by muse, mutect2, varscan2
- IL10RB | c.678C>T p.I226= | Silent (SNP) | VAF 47/212 reads (22%) | catalogued as COSV51616619; called by muse, mutect2, varscan2
- IREB2 | c.1266G>A p.Q422= | Silent (SNP) | VAF 11/44 reads (25%) | catalogued as COSV51924584; called by muse, mutect2, varscan2
- ITPRIP | c.963C>T p.F321= | Silent (SNP) | VAF 19/98 reads (19%) | catalogued as rs770920051, COSV53391425; called by muse, mutect2, varscan2
- KAT8 | c.1143C>T p.S381= | Silent (SNP) | VAF 10/66 reads (15%) | catalogued as rs1286107846, COSV54895151; called by muse, mutect2, varscan2
- KATNIP | c.2343C>T p.P781= | Silent (SNP) | VAF 31/136 reads (23%) | catalogued as rs369817858; called by muse, mutect2, varscan2
- KCNJ5 | c.729G>A p.Q243= | Silent (SNP) | VAF 31/130 reads (24%) | catalogued as COSV57968264; called by muse, mutect2, varscan2
- KEL | c.987G>A p.L329= | Silent (SNP) | VAF 38/229 reads (17%) | catalogued as COSV62336368; called by muse, mutect2, varscan2
- KERA | c.720C>T p.A240= | Silent (SNP) | VAF 22/93 reads (24%) | catalogued as COSV57131185; called by muse, mutect2, varscan2
- KHDRBS2 | c.474C>T p.F158= | Silent (SNP) | VAF 19/64 reads (30%) | catalogued as rs1356410327, COSV55434823, COSV55471432; called by muse, mutect2, varscan2
- KRT24 | c.321G>A p.G107= | Silent (SNP) | VAF 43/204 reads (21%) | catalogued as COSV52881002; called by muse, mutect2, varscan2
- KRT76 | c.447G>A p.G149= | Silent (SNP) | VAF 3/21 reads (14%) | catalogued as COSV60121080; called by muse, mutect2
- LAPTM5 | c.300C>T p.I100= | Silent (SNP) | VAF 9/50 reads (18%) | catalogued as COSV53852664; called by muse, mutect2, varscan2
- LBH | c.111G>A p.K37= | Silent (SNP) | VAF 15/51 reads (29%) | catalogued as COSV68049735; called by muse, mutect2, varscan2
- LENG9 | c.600C>T p.H200= | Silent (SNP) | VAF 24/62 reads (39%) | catalogued as COSV100002906; called by muse, mutect2, varscan2
- LGSN | c.882G>A p.R294= | Silent (SNP) | VAF 31/59 reads (53%) | catalogued as COSV65726364; called by muse, mutect2, varscan2
- LRBA | c.5625C>T p.I1875= | Silent (SNP) | VAF 18/89 reads (20%) | catalogued as rs370617816; called by muse, mutect2, varscan2
- LRP1B | c.2640C>T p.N880= | Silent (SNP) | VAF 13/64 reads (20%) | catalogued as rs1320343499, COSV63341852; called by muse, mutect2, varscan2
- MAB21L3 | c.240C>T p.A80= | Silent (SNP) | VAF 12/112 reads (11%) | catalogued as rs1458035578, COSV101046450; called by muse, mutect2, varscan2
- MACROD2 | c.531C>T p.I177= | Silent (SNP) | VAF 4/19 reads (21%) | catalogued as COSV54014238; called by muse, mutect2, varscan2
- MAGEB6 | c.810C>T p.L270= | Silent (SNP) | VAF 33/82 reads (40%) | catalogued as COSV66872606; called by muse, mutect2, varscan2
- MAML3 | c.3315C>T p.F1105= | Silent (SNP) | VAF 10/62 reads (16%) | catalogued as COSV72209630; called by muse, mutect2, varscan2
- MAPK13 | c.732G>A p.T244= | Silent (SNP) | VAF 11/51 reads (22%) | catalogued as rs527956493, COSV52982863; called by muse, mutect2, varscan2
- MAPKBP1 | c.1893G>A p.T631= (on ENST00000456763 / NM_001128608.2; = p.T625= on NM_014994.3) | Silent (SNP) | VAF 7/26 reads (27%) | catalogued as rs775194658, COSV52964336; called by muse, mutect2
- MDN1 | c.1572A>G p.A524= | Silent (SNP) | VAF 25/98 reads (26%) | catalogued as COSV65524979; called by muse, mutect2, varscan2
- MEF2C | c.1200C>T p.D400= | Silent (SNP) | VAF 8/43 reads (19%) | catalogued as COSV60934904; called by muse, mutect2, varscan2
- MGAM | c.2724G>A p.E908= | Silent (SNP) | VAF 27/75 reads (36%) | catalogued as COSV72075079; called by muse, mutect2, varscan2
- MRGPRX1 | c.603G>A p.R201= | Silent (SNP) | VAF 7/52 reads (13%) | catalogued as COSV57108562; called by muse, mutect2, varscan2
- MUC16 | c.36783C>T p.V12261= | Silent (SNP) | VAF 58/247 reads (23%) | catalogued as COSV67454060; called by muse, mutect2, varscan2
- MUC16 | c.35001G>A p.G11667= | Silent (SNP) | VAF 19/93 reads (20%) | catalogued as rs1378478790, COSV67478863; called by muse, mutect2, varscan2
- MUC16 | c.29397C>T p.I9799= | Silent (SNP) | VAF 20/70 reads (29%) | catalogued as COSV67478867; called by muse, mutect2, varscan2
- MUC16 | c.19140C>T p.S6380= | Silent (SNP) | VAF 16/60 reads (27%) | catalogued as COSV67478886; called by muse, mutect2, varscan2
- MUC16 | c.1911C>T p.S637= | Silent (SNP) | VAF 20/122 reads (16%) | catalogued as rs374207045, COSV101201319, COSV67495012; called by muse, mutect2, varscan2
- MUC5B | c.9138G>A p.R3046= | Silent (SNP) | VAF 23/127 reads (18%) | catalogued as rs369683007; called by muse, mutect2, varscan2
- MYBPHL | c.312G>A p.G104= | Silent (SNP) | VAF 18/83 reads (22%) | catalogued as COSV64062747; called by muse, mutect2, varscan2
- MYH1 | c.510G>A p.R170= | Silent (SNP) | VAF 26/78 reads (33%) | catalogued as COSV56852439; called by muse, mutect2, varscan2
- MYLK2 | c.327G>A p.K109= | Silent (SNP) | VAF 10/54 reads (19%) | catalogued as COSV101044763, COSV65659492; called by muse, mutect2, varscan2
- NAV2 | c.7110C>T p.L2370= (on ENST00000396087 / NM_001244963.2; = p.L2311= on NM_145117.5) | Silent (SNP) | VAF 56/263 reads (21%) | catalogued as COSV60658004; called by muse, mutect2, varscan2
- NCAN | c.2628G>A p.L876= | Silent (SNP) | VAF 23/127 reads (18%) | catalogued as COSV53054289; called by muse, mutect2, varscan2
- NCOA1 | c.1608C>T p.I536= | Silent (SNP) | VAF 13/78 reads (17%) | catalogued as COSV56040598; called by muse, mutect2, varscan2
- NEBL | c.1845G>A p.K615= | Silent (SNP) | VAF 32/193 reads (17%) | catalogued as COSV65804435; called by muse, mutect2, varscan2
- NELFA | c.330C>T p.S110= (on ENST00000542778; = p.S99= on NM_005663.5) | Silent (SNP) | VAF 26/132 reads (20%) | catalogued as COSV61606955; called by muse, mutect2, varscan2
- NEXMIF | c.495G>A p.L165= | Silent (SNP) | VAF 21/46 reads (46%) | catalogued as COSV50052990; called by muse, mutect2, varscan2
- NGFR | c.477C>T p.N159= | Silent (SNP) | VAF 4/43 reads (9%) | catalogued as COSV50803079; called by muse, mutect2
- NHSL2 | c.165G>A p.G55= (on ENST00000510661; = p.G421= on NM_001013627.2) | Silent (SNP) | VAF 17/30 reads (57%) | catalogued as COSV65454110; called by muse, mutect2, varscan2
- NLRP13 | c.2238C>T p.L746= | Silent (SNP) | VAF 15/102 reads (15%) | catalogued as COSV61622935; called by muse, mutect2, varscan2
- NLRP2 | c.1648C>T p.L550= | Silent (SNP) | VAF 44/88 reads (50%) | catalogued as COSV54757431; called by muse, mutect2, varscan2
- NLRP7 | c.2722C>T p.L908= (on ENST00000340844 / NM_206828.3; = p.L880= on NM_139176.3) | Silent (SNP) | VAF 47/125 reads (38%) | catalogued as COSV60177494; called by muse, mutect2, varscan2
- NMRK2 | c.147C>T p.D49= | Silent (SNP) | VAF 8/39 reads (21%) | catalogued as rs756765256, COSV99396485; called by muse, mutect2, varscan2
- NOBOX | c.720G>A p.G240= | Silent (SNP) | VAF 8/41 reads (20%) | catalogued as COSV56194573; called by muse, mutect2, varscan2
- NOS3 | c.900A>G p.P300= | Silent (SNP) | VAF 43/362 reads (12%) | catalogued as COSV99872032; called by muse, mutect2
- NOX5 | c.852C>T p.I284= | Silent (SNP) | VAF 5/23 reads (22%) | catalogued as COSV52992332; called by muse, mutect2, varscan2
- NSMCE3 | c.660G>A p.K220= | Silent (SNP) | VAF 17/86 reads (20%) | catalogued as COSV54278654; called by muse, mutect2, varscan2
- NTRK3 | c.2274G>A p.V758= (on ENST00000360948 / NM_001012338.2; = p.V744= on NM_002530.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 17/111 reads (15%) | catalogued as COSV62304383; called by muse, mutect2, varscan2
- OBSCN | c.19122C>T p.A6374= | Silent (SNP) | VAF 24/112 reads (21%) | catalogued as rs1268909753, COSV52797782; called by muse, mutect2, varscan2
- ODF3L1 | c.393C>T p.H131= | Silent (SNP) | VAF 51/315 reads (16%) | catalogued as COSV59820271, COSV59820411; called by muse, mutect2, varscan2
- OR10J3 | c.861C>T p.P287= | Silent (SNP) | VAF 17/128 reads (13%) | catalogued as COSV59955002; called by muse, mutect2, varscan2
- OR10X1 | c.789G>A p.V263= | Silent (SNP) | VAF 50/176 reads (28%) | catalogued as COSV63767647; called by muse, mutect2, varscan2
- OR2T10 | c.39C>T p.F13= | Silent (SNP) | VAF 12/62 reads (19%) | catalogued as COSV57897446; called by muse, mutect2, varscan2
- OR2W1 | c.684G>A p.T228= | Silent (SNP) | VAF 26/142 reads (18%) | catalogued as rs144276666, COSV65851448; called by muse, mutect2, varscan2
- OR52E6 | c.894A>G p.K298= | Silent (SNP) | VAF 21/99 reads (21%) | catalogued as COSV61432617; called by muse, mutect2, varscan2
- OR5AK2 | c.93C>T p.F31= | Silent (SNP) | VAF 18/118 reads (15%) | catalogued as rs1323884318, COSV58804872; called by muse, mutect2, varscan2
- OR5M10 | c.324G>A p.V108= | Silent (SNP) | VAF 19/79 reads (24%) | catalogued as COSV73242374, COSV73242378; called by muse, mutect2, varscan2
- OR7E24 | c.192C>T p.I64= | Silent (SNP) | VAF 14/69 reads (20%) | catalogued as rs1305535614, COSV71702278; called by muse, mutect2, varscan2
- OR9G4 | c.244C>T p.L82= | Silent (SNP) | VAF 43/144 reads (30%) | catalogued as rs747797303, COSV57249159; called by muse, mutect2, varscan2
- OS9 | c.1356C>T p.L452= | Silent (SNP) | VAF 14/70 reads (20%) | catalogued as COSV57783797; called by muse, mutect2, varscan2
- OTOGL | c.6621G>A p.G2207= (on ENST00000547103; = p.G2198= on NM_173591.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 21/80 reads (26%) | catalogued as COSV54019842; called by muse, mutect2, varscan2
- PACSIN1 | c.399G>A p.K133= | Silent (SNP) | VAF 33/140 reads (24%) | catalogued as COSV55061292; called by muse, mutect2, varscan2
- PC | c.1725G>A p.Q575= | Silent (SNP) | VAF 22/93 reads (24%) | catalogued as COSV58922153; called by muse, mutect2, varscan2
- PCDH12 | c.1599C>T p.F533= | Silent (SNP) | VAF 20/86 reads (23%) | catalogued as COSV51522759; called by muse, mutect2, varscan2
- PCDH9 | c.3522G>A p.V1174= (on ENST00000377865 / NM_203487.3; = p.V1140= on NM_020403.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 23/75 reads (31%) | catalogued as COSV60531135, COSV60568458; called by muse, mutect2, varscan2
- PCDHB10 | c.534C>T p.F178= | Silent (SNP) | VAF 53/239 reads (22%) | catalogued as COSV53381355; called by muse, mutect2, varscan2
- PCDHGA3 | c.1848C>T p.L616= | Silent (SNP) | VAF 14/82 reads (17%) | catalogued as COSV99544392; called by muse, varscan2
- PCDHGA9 | c.1692C>T p.Y564= | Silent (SNP) | VAF 32/226 reads (14%) | catalogued as COSV99544397; called by muse, mutect2, varscan2
- PCLO | c.2442C>T p.S814= | Silent (SNP) | VAF 61/184 reads (33%) | catalogued as COSV61648833; called by muse, mutect2, varscan2
- PCNT | c.4890G>A p.S1630= | Silent (SNP) | VAF 19/113 reads (17%) | catalogued as rs979435741; called by muse, mutect2, varscan2
- PDE1A | c.1473C>T p.S491= | Silent (SNP) | VAF 26/82 reads (32%) | catalogued as COSV59528693; called by muse, mutect2, varscan2
- PLEKHO1 | c.825C>T p.I275= | Silent (SNP) | VAF 8/67 reads (12%) | catalogued as rs1559964019, COSV50310718; called by muse, mutect2, varscan2
- PLVAP | c.738C>T p.I246= | Silent (SNP) | VAF 25/110 reads (23%) | catalogued as COSV53084020; called by muse, mutect2, varscan2
- POLD1 | c.2676C>T p.S892= | Silent (SNP) | VAF 16/39 reads (41%) | catalogued as rs1057523239, COSV54531798; ClinVar: likely benign; called by muse, mutect2, varscan2
- POLR3A | c.3078G>A p.Q1026= | Silent (SNP) | VAF 27/84 reads (32%) | catalogued as COSV64931486; called by muse, mutect2, varscan2
- POTEE | c.2724C>T p.I908= | Silent (SNP) | VAF 30/292 reads (10%) | catalogued as rs751948134, COSV58224990; called by muse, mutect2, varscan2
- PPARD | c.639C>T p.I213= | Silent (SNP) | VAF 16/57 reads (28%) | catalogued as COSV100283276; called by muse, mutect2, varscan2
- PPARG | c.669G>A p.A223= (on ENST00000287820 / NM_015869.5; = p.A193= on NM_005037.7) | Silent (SNP) | VAF 17/87 reads (20%) | catalogued as rs751812338, COSV55143193; ClinVar: uncertain significance; called by muse, mutect2, varscan2
115 further variants in this file (0 protein-altering or splice-affecting, 96 silent, 19 other) are not listed here.
